Somatic mutation profile of tumor specimen TCGA-A6-3809-01A (aliquot TCGA-A6-3809-01A-01D-A270-10) from TCGA case TCGA-A6-3809, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 71.9 years (26,274 days).
Specimen TCGA-A6-3809-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4afc3f29-3385-4df7-9dcc-913ce9cf1ae1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A6-3809-10A (Blood Derived Normal), aliquot TCGA-A6-3809-10A-01D-A270-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a8306f38-0f77-4c0f-9281-2838ce58af67

The open-access MAF lists 1,456 somatic variants for this specimen: 1,129 protein-altering or splice-affecting, 302 silent, 25 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 758, Silent 302, Frame Shift Del 251, Frame Shift Ins 39, Nonsense Mutation 34, Splice Site 19, In Frame Del 13, Splice Region 12, Intron 8, RNA 7, 3'UTR 5, 5'UTR 3.

Variants (750 of 1,456; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALMS1 | c.11083del p.S3695Afs*27 | Frame Shift Del (DEL) | VAF 33/163 reads (20%) | catalogued as rs1412574975, CM074695; ClinVar: uncertain significance / likely pathogenic; called by mutect2, pindel, varscan2
- ATP2A1 | c.2464del p.R822Gfs*49 | Frame Shift Del (DEL) | VAF 25/84 reads (30%) | catalogued as rs751365374, COSV62870629; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- ATP6V1B1 | c.1155del p.I386Sfs*10 | Frame Shift Del (DEL) | VAF 11/50 reads (22%) | catalogued as rs781969081; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- FBXW7 | c.1513C>T p.R505C (on ENST00000281708 / NM_001349798.2; = p.R425C on NM_018315.5) | Missense Mutation (SNP) | VAF 41/159 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149680468, COSV55890969, COSV55891274, COSV55898451; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FOXE3 | c.310C>T p.R104C | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755377651, COSV100624003; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KMT2B | c.521del p.P174Qfs*20 | Frame Shift Del (DEL) | VAF 38/121 reads (31%) | catalogued as rs763183959; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- MAGEL2 | c.1996del p.Q666Sfs*36 | Frame Shift Del (DEL) | VAF 4/38 reads (11%) | catalogued as rs770374710, CD1510958; ClinVar: pathogenic; called by mutect2, pindel
- MTM1 | c.969del p.V324* | Frame Shift Del (DEL) | VAF 48/235 reads (20%) | catalogued as rs587783865; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PCCA | c.923del p.L308Wfs*14 | Frame Shift Del (DEL) | VAF 40/126 reads (32%) | catalogued as rs573607437; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PKD1 | c.2085dup p.A696Rfs*18 | Frame Shift Ins (INS) | VAF 8/45 reads (18%) | catalogued as rs1567212531; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- SCN4A | c.737C>T p.S246L | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs80338951, COSV101438416; ClinVar: benign / pathogenic; called by muse, mutect2, varscan2
- SMPD1 | c.84del p.G29Dfs*48 | Frame Shift Del (DEL) | VAF 13/62 reads (21%) | catalogued as rs750157176; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- SPTA1 | c.143A>G p.K48R | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0.205); catalogued as rs121918644, CM910360; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- STK11 | c.842dup p.L282Afs*3 | Frame Shift Ins (INS) | VAF 11/54 reads (20%) | catalogued as rs121913321; ClinVar: pathogenic; called by mutect2, pindel
- TMPRSS6 | c.1786del p.A596Pfs*8 | Frame Shift Del (DEL) | VAF 24/88 reads (27%) | catalogued as rs767094129, CD082210; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- A1CF | c.238G>A p.G80S | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1392096112, COSV99255659; called by muse, mutect2, varscan2
- A2ML1 | c.3409C>G p.Q1137E | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT tolerated (0.39); PolyPhen benign (0.038); catalogued as COSV100228725; called by muse, mutect2, varscan2
- AAAS | c.745A>G p.S249G | Missense Mutation (SNP) | VAF 14/243 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.279); catalogued as COSV52933136; called by muse, mutect2
- AADACL2 | c.748G>A p.V250M | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.067); catalogued as rs369501242, COSV62932583; called by muse, mutect2, varscan2
- AAGAB | c.782A>G p.N261S | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.626); catalogued as COSV56016812; called by muse, mutect2, varscan2
- ABCB11 | c.1915A>G p.T639A | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.08); catalogued as COSV99791847; called by muse, mutect2, varscan2
- ABCB6 | c.35G>A p.G12E | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT tolerated (0.68); PolyPhen benign (0.019); catalogued as rs1410425747, COSV99521729; called by muse, mutect2, varscan2
- ABCD2 | c.239T>C p.V80A | Missense Mutation (SNP) | VAF 61/148 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0.031); catalogued as COSV100429280; called by muse, mutect2, varscan2
- ABL2 | c.416A>G p.Y139C (on ENST00000502732 / NM_007314.4; = p.Y124C on NM_005158.5) | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs908816677, COSV100772620; called by muse, mutect2, varscan2
- AC144573.1 | c.770C>T p.T257I | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious, low confidence (0); catalogued as COSV100294404; called by muse, mutect2, varscan2
- ACVR1B | c.1439A>G p.N480S | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.396); catalogued as COSV99231366; called by muse, mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 45/84 reads (54%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ACVR2B | c.716T>C p.M239T | Missense Mutation (SNP) | VAF 45/148 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV61702153; called by muse, mutect2, varscan2
- ADAM22 | c.863T>C p.V288A | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55975695; called by muse, mutect2
- ADAMTS10 | c.2156C>T p.A719V | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.1); catalogued as COSV99546708; called by muse, mutect2, varscan2
- ADAMTS15 | c.743C>T p.T248M | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.936); catalogued as rs759898564, COSV100143255; called by muse, mutect2, varscan2
- ADAMTS2 | c.2210-2del p.X737_splice | Splice Site (DEL) | VAF 13/49 reads (27%) | catalogued as rs1219329381; called by mutect2, pindel, varscan2
- ADAMTSL5 | c.376G>A p.D126N | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as rs1185497645, COSV100389120; called by muse, mutect2, varscan2
- ADCY8 | c.448C>T p.R150* | Nonsense Mutation (SNP) | VAF 12/56 reads (21%) | catalogued as COSV99651556; called by muse, mutect2, varscan2
- ADD3 | c.2025A>C p.E675D (on ENST00000356080 / NM_001320591.2; = p.E643D on NM_001121.4) | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV99523300; called by muse, mutect2, varscan2
- ADGRB1 | c.1135C>T p.R379C | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as COSV60095751; called by muse, mutect2, varscan2
- ADGRG4 | c.7714del p.D2572Tfs*24 | Frame Shift Del (DEL) | VAF 15/77 reads (19%) | catalogued as COSV54953670, COSV54960507; called by mutect2, pindel, varscan2
- ADGRL1 | c.818A>G p.D273G (on ENST00000340736 / NM_001008701.3; = p.D268G on NM_014921.5) | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1387965213, COSV61566424; called by muse, mutect2, varscan2
- ADGRV1 | c.3565C>A p.L1189I | Missense Mutation (SNP) | VAF 45/145 reads (31%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.969); catalogued as COSV101315704; called by muse, mutect2, varscan2
- ADRA1D | c.641C>T p.A214V | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT tolerated (0.76); PolyPhen benign (0.173); catalogued as rs1442709524, COSV101062945; called by muse, mutect2
- AEBP1 | c.425C>T p.P142L | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV56256987; called by muse, mutect2
- AEBP2 | c.1325C>A p.S442Y | Missense Mutation (SNP) | VAF 24/200 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.915); catalogued as COSV56862844, COSV56863268; called by muse, mutect2, varscan2
- AFAP1L1 | c.529A>G p.S177G | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV99695787; called by muse, mutect2, varscan2
- AFF2 | c.1173G>T p.Q391H | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as rs929635504, COSV99662967; called by muse, mutect2, varscan2
- AFF3 | c.3139A>C p.T1047P | Missense Mutation (SNP) | VAF 28/105 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV100418471; called by muse, mutect2, varscan2
- AFM | c.738del p.K246Nfs*14 | Frame Shift Del (DEL) | VAF 21/105 reads (20%) | catalogued as rs985591151; called by mutect2, pindel, varscan2
- AGK | c.589G>T p.G197C | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV100814594; called by muse, mutect2, varscan2
- AKAP11 | c.133T>C p.C45R | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.01); catalogued as COSV99213729; called by muse, mutect2, varscan2
- AKT1 | c.574G>A p.V192M | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV100838072; called by muse, mutect2, varscan2
- AL592490.1 | c.256G>A p.A86T | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.057); catalogued as rs1300701763, COSV69426007; called by muse, mutect2, varscan2
- ALDH3B1 | c.922C>T p.Q308* | Nonsense Mutation (SNP) | VAF 28/94 reads (30%) | catalogued as COSV99141706; called by muse, varscan2
- ALG8 | c.206del p.P69Lfs*22 | Frame Shift Del (DEL) | VAF 32/118 reads (27%) | catalogued as CM098505; called by mutect2, varscan2
- ALPK3 | c.341A>G p.D114G | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as COSV99360615; called by muse, mutect2
- AMIGO2 | c.316A>G p.T106A | Missense Mutation (SNP) | VAF 67/141 reads (48%) | SIFT tolerated (0.55); PolyPhen benign (0.007); catalogued as COSV99873546; called by muse, mutect2, varscan2
- ANK1 | c.4406C>T p.T1469I | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.013); catalogued as rs757079520, COSV99224704; called by muse, mutect2, varscan2
- ANK2 | c.9682G>A p.V3228M | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT tolerated, low confidence (0.97); PolyPhen benign (0); catalogued as rs141013157; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANK3 | c.9349del p.I3117Sfs*2 | Frame Shift Del (DEL) | VAF 25/91 reads (27%) | catalogued as rs370637835; called by mutect2, varscan2
- ANKH | c.851C>A p.P284H | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99414800; called by muse, mutect2, varscan2
- ANKRD11 | c.7535G>A p.R2512Q | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM150409, COSV99968877; called by muse, mutect2, varscan2
- ANKRD11 | c.4906G>A p.D1636N | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.466); catalogued as COSV99968878; called by muse, mutect2, varscan2
- ANKRD26 | c.4976dup p.N1659Kfs*4 | Frame Shift Ins (INS) | VAF 24/78 reads (31%) | catalogued as rs762275496; called by mutect2, varscan2
- ANKRD44 | c.2225A>G p.Y742C | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.704); catalogued as COSV99984582; called by muse, mutect2, varscan2
- ANO4 | c.2311T>C p.Y771H (on ENST00000392977 / NM_001286615.2; = p.Y736H on NM_178826.4) | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT tolerated (0.4); PolyPhen benign (0.176); catalogued as rs1353801712, COSV54598702; called by muse, mutect2, varscan2
- ANTKMT | c.705C>A p.S235R | Missense Mutation (SNP) | VAF 16/26 reads (62%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as COSV99557302; called by muse, mutect2, varscan2
- ANXA6 | c.1458G>T p.E486D | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.258); catalogued as rs1343623811, COSV62906509; called by muse, mutect2, varscan2
- AP1M1 | c.223G>A p.A75T | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.4); PolyPhen benign (0.145); catalogued as rs749998518, COSV99358314; called by muse, mutect2, varscan2
- APBA1 | c.1952C>T p.S651L | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs756578388, COSV99595789; called by muse, mutect2, varscan2
- APC2 | c.3224C>T p.S1075L | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765851523, COSV99279313; called by muse, mutect2, varscan2
- AQP7 | c.700del p.R234Afs*34 | Frame Shift Del (DEL) | VAF 11/51 reads (22%) | catalogued as rs3215969; called by mutect2, pindel, varscan2
- ARAP2 | c.4519A>G p.T1507A | Missense Mutation (SNP) | VAF 57/183 reads (31%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.715); catalogued as COSV58294469; called by muse, mutect2, varscan2
- ARFGEF3 | c.2332C>A p.L778M | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.088); catalogued as COSV99292957; called by muse, mutect2, varscan2
- ARHGAP20 | c.724T>A p.Y242N | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV99503594; called by muse, mutect2, varscan2
- ARHGAP22 | c.878A>G p.E293G | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99984933; called by muse, mutect2, varscan2
- ARHGAP24 | c.1856G>A p.R619Q (on ENST00000395184 / NM_001025616.3; = p.R526Q on NM_031305.3) | Missense Mutation (SNP) | VAF 37/103 reads (36%) | SIFT tolerated (0.49); PolyPhen benign (0.115); catalogued as rs759004152, COSV99981952; called by muse, mutect2, varscan2
- ARHGEF4 | c.871G>A p.E291K | Missense Mutation (SNP) | VAF 37/106 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100387879; called by muse, mutect2, varscan2
- ARL2BP | c.46G>A p.A16T | Missense Mutation (SNP) | VAF 38/129 reads (29%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as COSV99536001; called by muse, mutect2, varscan2
- ARL6IP6 | c.325C>A p.L109I | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.888); catalogued as COSV100423931; called by muse, mutect2, varscan2
- ARVCF | c.2051C>T p.A684V | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as COSV99599102; called by muse, mutect2, varscan2
- ASCC3 | c.489del p.F163Lfs*5 | Frame Shift Del (DEL) | VAF 18/89 reads (20%) | catalogued as rs747570359; called by mutect2, varscan2
- ASPA | c.918A>C p.K306N | Missense Mutation (SNP) | VAF 5/103 reads (5%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV99559189; called by muse, mutect2
- ASTN2 | c.2549G>T p.G850V (on ENST00000313400 / NM_001365069.1; = p.G799V on NM_014010.5) | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100526105; called by muse, mutect2, varscan2
- ATAD2B | c.2756C>A p.P919Q | Missense Mutation (SNP) | VAF 26/116 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV99477345; called by muse, mutect2, varscan2
- ATG9B | c.1187T>C p.L396P | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99871435; called by muse, mutect2
- ATP1A2 | c.587G>A p.R196H | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs1392328953, COSV63405509; called by muse, mutect2, varscan2
- ATP1B4 | c.478G>A p.A160T (on ENST00000218008 / NM_001142447.3; = p.A156T on NM_012069.5) | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT tolerated (0.72); PolyPhen benign (0.081); catalogued as rs781753966, COSV54311680; called by muse, mutect2, varscan2
- ATP2A3 | c.2155G>A p.A719T | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV59230581; called by muse, mutect2, varscan2
- ATP2B3 | c.2747G>A p.R916H | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1557015474, COSV54845611; called by muse, mutect2, varscan2
- ATP6V0A4 | c.868G>A p.A290T | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.113); catalogued as COSV59479580; called by muse, mutect2, varscan2
- B3GNT6 | c.673G>A p.V225M | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100845762; called by muse, mutect2, varscan2
- B4GALNT4 | c.2972del p.G991Vfs*71 | Frame Shift Del (DEL) | VAF 4/40 reads (10%) | catalogued as rs35951843; called by pindel, varscan2
- BAHCC1 | c.1330C>A p.L444M | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.135); catalogued as COSV100311414; called by muse, mutect2, varscan2
- BAHCC1 | c.1526A>G p.Q509R | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.69); catalogued as rs782461900, COSV57026008; called by muse, varscan2
- BANK1 | c.1969+1G>T p.X657_splice | Splice Site (SNP) | VAF 20/81 reads (25%) | catalogued as COSV100536142; called by muse, mutect2, varscan2
- BBX | c.1738A>G p.M580V | Missense Mutation (SNP) | VAF 59/225 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs1265533064, COSV100361297; called by muse, mutect2, varscan2
- BCAN | c.2513C>T p.T838I | Missense Mutation (SNP) | VAF 37/107 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as COSV100227998; called by muse, mutect2, varscan2
- BCCIP | c.325A>G p.T109A | Missense Mutation (SNP) | VAF 31/105 reads (30%) | SIFT tolerated (0.75); PolyPhen benign (0.02); catalogued as COSV99532950; called by muse, mutect2, varscan2
- BCL9 | c.1026dup p.T343Hfs*34 | Frame Shift Ins (INS) | VAF 9/54 reads (17%) | catalogued as rs1553204401; called by mutect2, pindel, varscan2
- BCOR | c.3331C>T p.P1111S | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT tolerated (0.55); PolyPhen benign (0.038); catalogued as rs371897880, COSV100653109; called by muse, mutect2, varscan2
- BCORL1 | c.5042dup p.G1682Rfs*4 | Frame Shift Ins (INS) | VAF 18/60 reads (30%) | catalogued as rs768244116, COSV54407680; called by mutect2, varscan2
- BCR | c.2638C>T p.Q880* | Nonsense Mutation (SNP) | VAF 22/71 reads (31%) | catalogued as COSV100006314; called by muse, mutect2, varscan2
- BEND2 | c.1580A>G p.H527R | Missense Mutation (SNP) | VAF 58/191 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.033); catalogued as COSV101191918; called by muse, mutect2, varscan2
- BEST3 | c.45del p.F15Lfs*32 | Frame Shift Del (DEL) | VAF 23/198 reads (12%) | catalogued as rs1184020574; called by mutect2, pindel, varscan2
- BET1 | c.42C>A p.N14K | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV99747230; called by muse, mutect2, varscan2
- BHLHE40 | c.33del p.A12Pfs*32 | Frame Shift Del (DEL) | VAF 25/91 reads (27%) | catalogued as rs868723963; called by mutect2, pindel, varscan2
- BIRC3 | c.343T>G p.S115A | Missense Mutation (SNP) | VAF 41/130 reads (32%) | SIFT tolerated (0.85); PolyPhen benign (0.005); catalogued as COSV54816374; called by muse, mutect2, varscan2
- BIRC6 | c.4612C>A p.L1538I | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.044); catalogued as COSV101428082, COSV101429134; called by muse, mutect2, varscan2
- BLM | c.2268del p.D757Tfs*4 | Frame Shift Del (DEL) | VAF 92/320 reads (29%) | catalogued as rs747341586; called by mutect2, varscan2
- BMF | c.386C>T p.A129V | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as COSV55019025; called by muse, mutect2, varscan2
- BMP2 | c.106G>T p.A36S | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs752683518, COSV66577006, COSV66578595; called by muse, varscan2
- BMPR2 | c.853-1G>T p.X285_splice | Splice Site (SNP) | VAF 15/52 reads (29%) | catalogued as CS085038, CS1513975, COSV101001390; called by muse, varscan2
- BMPR2 | c.2329C>T p.H777Y | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (1); PolyPhen possibly damaging (0.574); catalogued as rs773965156, COSV101001392; called by muse, mutect2, varscan2
- BNIP2 | c.497C>T p.A166V | Missense Mutation (SNP) | VAF 15/392 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV99985697; called by muse, mutect2
- BRD3 | c.71del p.P24Rfs*24 | Frame Shift Del (DEL) | VAF 8/33 reads (24%) | catalogued as rs763134487; called by mutect2, varscan2
- BRINP3 | c.1943C>T p.P648L | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1172552823, COSV100818606; called by muse, mutect2, varscan2
- BRMS1L | c.308T>C p.L103S | Missense Mutation (SNP) | VAF 72/254 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV99396603; called by muse, mutect2, varscan2
- BRPF1 | c.1334A>G p.D445G | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.434); catalogued as COSV100121178; called by muse, mutect2, varscan2
- C16orf72 | c.811C>T p.R271C | Missense Mutation (SNP) | VAF 34/97 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs781070790, COSV59915931; called by muse, mutect2, varscan2
- C18orf25 | c.1031T>C p.V344A | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (0.6); PolyPhen benign (0.007); catalogued as COSV56365093; called by muse, mutect2, varscan2
- C19orf44 | c.26G>A p.R9H | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs762331456, COSV99522121; called by muse, mutect2, varscan2
- C3orf20 | c.1191G>C p.Q397H | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99513679; called by muse, mutect2, varscan2
- C8orf34 | c.727C>A p.L243I | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV61378113, COSV61380370; called by muse, mutect2, varscan2
- CABP7 | c.541C>T p.R181C | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.847); catalogued as rs762471805, COSV53362629; called by muse, mutect2, varscan2
- CACNA1B | c.2122G>A p.A708T | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53124965; called by muse, mutect2, varscan2
- CACNA1F | c.2075G>T p.S692I | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.712); catalogued as COSV100544600; called by muse, mutect2, varscan2
- CAMK1D | c.830C>A p.P277Q | Missense Mutation (SNP) | VAF 27/112 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV101123609; called by muse, mutect2, varscan2
- CAPN15 | c.1090G>A p.G364S | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1304213547, COSV99562322; called by muse, mutect2, varscan2
- CAPRIN1 | c.1999C>T p.R667W | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV100403709, COSV58219658; called by muse, mutect2, varscan2
- CARD19 | c.158A>G p.N53S | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.12); catalogued as COSV100968655; called by muse, mutect2, varscan2
- CARMIL1 | c.3193C>T p.R1065W | Missense Mutation (SNP) | VAF 40/144 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs753444416, COSV61524570; called by muse, mutect2, varscan2
- CARMIL3 | c.3598G>A p.G1200R | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99393273; called by muse, mutect2, varscan2
- CARS1 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 38/136 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.023); catalogued as rs761521860, COSV99542414; called by muse, mutect2, varscan2
- CASKIN2 | c.1622_1624del p.K541del | In Frame Del (DEL) | VAF 4/23 reads (17%) | catalogued as rs1478974955; called by pindel, varscan2
- CATSPER2 | c.842+1G>A p.X281_splice | Splice Site (SNP) | VAF 9/37 reads (24%) | catalogued as rs199516208, COSV58660954, COSV58661550; called by muse, mutect2, varscan2
- CATSPERD | c.1069C>T p.R357C | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.556); catalogued as rs766938408, COSV58464752; called by muse, mutect2, varscan2
- CBWD5 | c.258A>C p.K86N | Missense Mutation (SNP) | VAF 148/1265 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101070715; called by muse, varscan2
- CCDC148 | c.1251del p.I418* | Frame Shift Del (DEL) | VAF 10/21 reads (48%) | catalogued as rs758917400; called by mutect2, varscan2
- CCDC185 | c.373A>G p.T125A | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.77); PolyPhen benign (0.006); catalogued as COSV100838782; called by muse, mutect2, varscan2
- CCDC85A | c.201G>A p.M67I | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.706); catalogued as COSV101339437; called by muse, mutect2, varscan2
- CCDC88A | c.2335del p.I779Sfs*4 | Frame Shift Del (DEL) | VAF 12/51 reads (24%) | catalogued as COSV55059558; called by mutect2, pindel, varscan2
- CCDC91 | c.1079A>G p.Q360R | Missense Mutation (SNP) | VAF 50/192 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV100081586; called by muse, mutect2, varscan2
- CCDC96 | c.721C>T p.R241C | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as COSV100027869; called by muse, mutect2, varscan2
- CCHCR1 | c.1799-3del | Splice Region (DEL) | VAF 9/39 reads (23%) | catalogued as rs768163698; called by mutect2, pindel, varscan2
- CCND2 | c.318G>C p.M106I | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.028); catalogued as COSV99714133; called by muse, mutect2, varscan2
- CCNJL | c.1066G>A p.A356T | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.804); catalogued as COSV99979395; called by muse, mutect2, varscan2
- CD70 | c.233del p.G78Afs*33 | Frame Shift Del (DEL) | VAF 8/29 reads (28%) | catalogued as COSV99835502; called by mutect2, pindel, varscan2
- CDC37 | c.358A>G p.S120G | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.579); catalogued as COSV99705742; called by muse, mutect2, varscan2
- CDC73 | c.563A>C p.K188T | Missense Mutation (SNP) | VAF 57/197 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100813777; called by muse, mutect2, varscan2
- CDH11 | c.844G>A p.V282I | Missense Mutation (SNP) | VAF 36/120 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs367827121; called by muse, mutect2
- CDH23 | c.2083G>A p.A695T | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV99820077; called by muse, mutect2, varscan2
- CDK5R2 | c.295C>T p.R99C | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.96); catalogued as COSV100225875; called by muse, mutect2, varscan2
- CEACAM5 | c.1808C>T p.S603L | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT tolerated (0.21); PolyPhen benign (0.031); catalogued as rs781903049, COSV99703829; called by muse, mutect2
- CEMIP | c.3226G>A p.D1076N | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.03); catalogued as rs1159120769, COSV54997158; called by muse, mutect2, varscan2
- CENPA | c.203G>A p.S68N | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.787); catalogued as COSV99273176; called by muse, mutect2
- CENPB | c.869G>A p.R290H | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV100713364; called by muse, mutect2, varscan2
- CENPF | c.143T>C p.L48P | Missense Mutation (SNP) | VAF 40/151 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100871626; called by muse, mutect2, varscan2
- CENPU | c.1132G>A p.V378I | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs200975207; called by muse, mutect2, varscan2
- CFAP77 | c.938G>A p.R313Q | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.643); catalogued as rs754054268, COSV58006820, COSV58017254; called by muse, varscan2
- CFH | c.3445C>T p.R1149* | Nonsense Mutation (SNP) | VAF 68/244 reads (28%) | catalogued as rs1354315554, CM1314325, COSV66410123; called by muse, mutect2, varscan2
- CHD7 | c.7129A>G p.S2377G | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV101418133; called by muse, mutect2, varscan2
- CHD8 | c.7429A>C p.M2477L (on ENST00000646647 / NM_001170629.2; = p.M2198L on NM_020920.4) | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.039); catalogued as COSV99359766; called by muse, mutect2
- CHML | c.695A>T p.D232V | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1318920385, COSV100087227; called by muse, mutect2, varscan2
- CHRM5 | c.571C>T p.P191S | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101271889; called by muse, mutect2, varscan2
- CHST10 | c.488G>A p.G163D | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.986); catalogued as COSV99958819; called by muse, mutect2, varscan2
- CHST12 | c.661C>T p.R221C | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99324400; called by muse, mutect2, varscan2
- CHST15 | c.1192T>G p.L398V | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.281); catalogued as COSV100655041; called by muse, mutect2, varscan2
- CHST6 | c.1031G>A p.R344H | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.908); catalogued as COSV100178344; called by muse, mutect2, varscan2
- CHST8 | c.570C>A p.H190Q | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV52858676, COSV99380929; called by muse, mutect2, varscan2
- CIB3 | c.406A>G p.T136A | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); catalogued as rs1396628976, COSV99521750; called by muse, mutect2, varscan2
- CIT | c.1808C>T p.A603V | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.48); PolyPhen benign (0.148); catalogued as rs141341431; called by muse, mutect2, varscan2
- CLDND1 | c.535C>A p.L179I | Missense Mutation (SNP) | VAF 44/143 reads (31%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.772); catalogued as COSV100360694, COSV57858727; called by muse, mutect2, varscan2
- CLEC3A | c.397G>T p.G133C (on ENST00000651443; = p.G124C on NM_005752.6) | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.944); catalogued as COSV100222158, COSV55219791; called by muse, mutect2
- CLIP2 | c.1042G>A p.A348T | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as rs1347480501, COSV99791293; called by muse, mutect2, varscan2
- CLPP | c.28del p.A10Pfs*117 | Frame Shift Del (DEL) | VAF 6/24 reads (25%) | catalogued as rs770403079; called by mutect2, pindel, varscan2
- CMBL | c.468C>T p.G156= | Splice Region (SNP) | VAF 31/123 reads (25%) | catalogued as rs1320800485, COSV56984873, COSV99686979; called by muse, mutect2, varscan2
- CNBD1 | c.233A>C p.K78T | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.049); catalogued as COSV101572857; called by muse, mutect2, varscan2
- CNGB1 | c.656T>C p.I219T | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.001); catalogued as COSV99202288; called by muse, mutect2, varscan2
- CNST | c.1409C>T p.A470V | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.024); catalogued as rs145890214; called by muse, mutect2, varscan2
- CNTNAP2 | c.215G>A p.G72E | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62184332; called by muse, mutect2, varscan2
- COL11A1 | c.67G>A p.A23T | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs1386580787, COSV62181718; called by muse, mutect2, varscan2
- COL14A1 | c.4771G>A p.A1591T | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.009); catalogued as rs370064596; called by muse, mutect2, varscan2
- COL18A1 | c.4045G>A p.G1349S (on ENST00000359759 / NM_130444.3; = p.G1114S on NM_030582.4) | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT tolerated (0.28); PolyPhen benign (0.013); catalogued as rs775944368, COSV60590453; called by muse, mutect2, varscan2
- COL25A1 | c.1488del p.G497Efs*14 | Frame Shift Del (DEL) | VAF 17/55 reads (31%) | catalogued as COSV101211681; called by mutect2, pindel, varscan2
- COL4A4 | c.1897G>T p.G633* | Nonsense Mutation (SNP) | VAF 23/76 reads (30%) | catalogued as COSV100306531, COSV100307557; called by muse, mutect2, varscan2
- COL4A6 | c.330C>T p.G110= | Splice Region (SNP) | VAF 19/59 reads (32%) | catalogued as COSV100563813; called by muse, mutect2, varscan2
- COL6A3 | c.6312C>T p.G2104= | Splice Region (SNP) | VAF 46/129 reads (36%) | catalogued as rs377074792; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL6A6 | c.4217G>T p.R1406M | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.353); catalogued as COSV100650112; called by muse, mutect2, varscan2
- COL8A1 | c.305A>G p.E102G | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV53733751; called by muse, mutect2, varscan2
- COLEC12 | c.1968del p.K656Nfs*4 | Frame Shift Del (DEL) | VAF 18/66 reads (27%) | catalogued as COSV101232229; called by mutect2, varscan2
- COQ8A | c.611G>A p.R204Q | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.506); catalogued as rs200541514; called by muse, mutect2, varscan2
- COQ8A | c.1822T>C p.S608P | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100504399; called by muse, mutect2, varscan2
- CORO7 | c.2153C>T p.A718V | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.261); catalogued as COSV99227441; called by muse, mutect2, varscan2
- CPAMD8 | c.1382C>T p.T461M (on ENST00000651564; = p.T414M on NM_015692.5) | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0.039); catalogued as rs192285706, COSV99359195; called by muse, mutect2, varscan2
- CPLANE1 | c.8510T>C p.V2837A | Missense Mutation (SNP) | VAF 49/124 reads (40%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as COSV99950151; called by muse, mutect2, varscan2
- CPXM1 | c.1645C>T p.R549* | Nonsense Mutation (SNP) | VAF 10/29 reads (34%) | catalogued as rs751762428, COSV101013703; called by muse, mutect2, varscan2
- CRACD | c.3178G>A p.G1060R | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.814); catalogued as rs1336165783, COSV99948949, COSV99949367; called by muse, mutect2, varscan2
- CRB2 | c.35A>G p.Q12R | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV100749589; called by muse, mutect2, varscan2
- CRCT1 | c.64G>A p.A22T | Missense Mutation (SNP) | VAF 5/18 reads (28%) | PolyPhen benign (0.005); catalogued as COSV100524216; called by muse, mutect2, varscan2
- CREBBP | c.3250del p.I1084Sfs*15 | Frame Shift Del (DEL) | VAF 16/74 reads (22%) | catalogued as rs1378599948; called by mutect2, pindel, varscan2
- CROCC | c.4566G>T p.Q1522H | Missense Mutation (SNP) | VAF 35/113 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as COSV100978132; called by muse, mutect2, varscan2
- CRYZ | c.388G>A p.G130S | Missense Mutation (SNP) | VAF 35/114 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.303); catalogued as rs1037440251, COSV61717610; called by muse, mutect2, varscan2
- CSF3R | c.709C>A p.P237T | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0.045); catalogued as COSV100117503; called by muse, mutect2, varscan2
- CSMD3 | c.7140T>G p.S2380R (on ENST00000297405 / NM_001363185.1; = p.S2276R on NM_052900.3) | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV99830256; called by muse, mutect2, varscan2
- CSNK1E | c.385G>A p.V129I | Missense Mutation (SNP) | VAF 38/152 reads (25%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.007); catalogued as COSV100725012; called by muse, mutect2, varscan2
- CSNK1G2 | c.695G>A p.R232H | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99729774; called by muse, mutect2, varscan2
- CSNK2A2 | c.47T>C p.V16A | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0.039); catalogued as COSV99345249; called by muse, mutect2, varscan2
- CTBP2 | c.449C>T p.T150M | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.997); catalogued as rs771702203, COSV100456311, COSV58333657; called by muse, mutect2, varscan2
- CYB5RL | c.931T>G p.S311A | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as COSV55277251; called by muse, mutect2, varscan2
- CYLC1 | c.1312A>T p.K438* | Nonsense Mutation (SNP) | VAF 85/314 reads (27%) | catalogued as COSV100254361; called by muse, mutect2, varscan2
- CYP3A4 | c.216G>T p.W72C | Missense Mutation (SNP) | VAF 41/143 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.556); catalogued as COSV100315560; called by muse, mutect2, varscan2
- CYP8B1 | c.401A>G p.D134G | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.035); catalogued as COSV60225765; called by muse, mutect2, varscan2
- DBF4 | c.74dup p.N25Kfs*11 | Frame Shift Ins (INS) | VAF 44/140 reads (31%) | catalogued as rs762918884; called by mutect2, varscan2
- DCDC2B | c.1024G>A p.A342T | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.007); catalogued as rs1557537140, COSV59084371; called by muse, mutect2, varscan2
- DCHS1 | c.548C>T p.S183F | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV100201863; called by muse, mutect2, varscan2
- DCP1B | c.992C>A p.P331H | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.436); catalogued as COSV99767395; called by muse, mutect2, varscan2
- DCTN5 | c.176G>A p.R59H | Missense Mutation (SNP) | VAF 35/146 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.092); catalogued as rs1403723804, COSV100265927; called by muse, mutect2, varscan2
- DDHD1 | c.748G>A p.A250T (on ENST00000323669; = p.A447T on NM_030637.3) | Missense Mutation (SNP) | VAF 8/134 reads (6%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as rs1408668280, COSV100079332; called by muse, mutect2
- DDX28 | c.356T>C p.V119A | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV100192952; called by mutect2, varscan2
- DENND11 | c.995A>T p.D332V | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101530707; called by muse, mutect2, varscan2
- DENND4B | c.22del p.R8Gfs*8 | Frame Shift Del (DEL) | VAF 9/36 reads (25%) | catalogued as rs755611865; called by mutect2, pindel, varscan2
- DENND5A | c.2917G>A p.A973T | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.403); catalogued as COSV100064398; called by muse, mutect2, varscan2
- DEUP1 | c.443C>T p.A148V | Missense Mutation (SNP) | VAF 41/136 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.023); catalogued as COSV99976971; called by muse, mutect2, varscan2
- DGKI | c.2816T>G p.L939R | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.434); catalogued as COSV99933336; called by muse, mutect2, varscan2
- DGKI | c.769C>T p.R257C | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs767534902, COSV99068403, COSV99933339; called by muse, varscan2
- DHRS7C | c.595G>T p.A199S (on ENST00000330255 / NM_001220493.2; = p.A198S on NM_001105571.3) | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.458); catalogued as COSV57650562; called by muse, mutect2, varscan2
- DHX16 | c.1723C>T p.R575C | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200255671, COSV100905169; called by muse, mutect2, varscan2
- DHX36 | c.460del p.M154Cfs*27 | Frame Shift Del (DEL) | VAF 53/160 reads (33%) | catalogued as rs373108427; called by mutect2, varscan2
- DHX8 | c.1846A>G p.T616A | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99292076; called by muse, mutect2, varscan2
- DIAPH2 | c.31G>A p.A11T | Missense Mutation (SNP) | VAF 45/165 reads (27%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0); catalogued as COSV100232090; called by muse, mutect2, varscan2
- DIDO1 | c.3826C>A p.L1276M | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.123); catalogued as COSV99825377, COSV99827103; called by muse, mutect2, varscan2
- DISP3 | c.3794A>G p.N1265S | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.37); PolyPhen benign (0.005); catalogued as rs1293712451, COSV99608070; called by muse, mutect2
- DKK1 | c.187G>A p.A63T | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as rs761830028, COSV100906521, COSV64759956; called by muse, mutect2, varscan2
- DLGAP1 | c.2204G>A p.S735N | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.026); catalogued as rs748938600, COSV100229278; called by muse, mutect2, varscan2
- DLGAP2 | c.1102C>T p.R368C | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1192026977, COSV101421549; called by muse, mutect2, varscan2
- DMRT2 | c.86C>T p.A29V | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as rs1025069041, COSV52401730; called by muse, mutect2, varscan2
- DMXL2 | c.2981C>T p.T994M | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs770583176, COSV99196165; called by muse, mutect2, varscan2
- DNAH1 | c.11570T>C p.L3857P | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99963727; called by muse, mutect2, varscan2
- DNAH11 | c.13240dup p.T4414Nfs*34 | Frame Shift Ins (INS) | VAF 30/92 reads (33%) | catalogued as rs759332741; called by mutect2, varscan2
- DNAH2 | c.1460A>G p.H487R | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV99318056; called by muse, mutect2, varscan2
- DNAH8 | c.6695G>A p.R2232H | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59426561; called by muse, mutect2, varscan2
- DNAH9 | c.7949del p.P2650Hfs*2 | Frame Shift Del (DEL) | VAF 10/53 reads (19%) | catalogued as COSV52362670; called by mutect2, varscan2
- DNAI2 | c.835G>A p.E279K | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs746323026, COSV56758894; called by muse, mutect2, varscan2
- DNAJC13 | c.4832G>T p.G1611V | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.058); catalogued as COSV53449687; called by muse, mutect2, varscan2
- DNAJC16 | c.1794del p.G599Afs*5 | Frame Shift Del (DEL) | VAF 17/60 reads (28%) | catalogued as rs756910133; called by mutect2, pindel, varscan2
- DNMBP | c.1868C>A p.P623H | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.156); catalogued as COSV100143450; called by muse, mutect2, varscan2
- DOC2A | c.191del p.P64Lfs*27 | Frame Shift Del (DEL) | VAF 6/51 reads (12%) | catalogued as rs753153258; called by mutect2, pindel, varscan2
- DOCK10 | c.1272del p.F424Lfs*2 | Frame Shift Del (DEL) | VAF 13/50 reads (26%) | catalogued as rs1559599687; called by mutect2, pindel, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 13/46 reads (28%) | catalogued as rs782552436; called by mutect2, pindel, varscan2
- DOCK4 | c.4040C>T p.A1347V | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.916); catalogued as COSV101445596; called by muse, mutect2, varscan2
- DOP1A | c.28A>T p.S10C | Missense Mutation (SNP) | VAF 22/129 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.797); catalogued as COSV99381508; called by muse, mutect2, varscan2
- DOP1A | c.6080A>T p.N2027I | Missense Mutation (SNP) | VAF 28/130 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as COSV99381514; called by muse, mutect2, varscan2
- DOP1B | c.4135C>T p.Q1379* | Nonsense Mutation (SNP) | VAF 19/65 reads (29%) | catalogued as COSV101215216; called by muse, mutect2, varscan2
- DSC3 | c.851T>G p.I284S | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100844564; called by muse, mutect2, varscan2
- DSN1 | c.183del p.G63Efs*39 | Frame Shift Del (DEL) | VAF 14/70 reads (20%) | catalogued as rs35111724, COSV101041127; called by mutect2, pindel, varscan2
- DSPP | c.2075G>A p.S692N | Missense Mutation (SNP) | VAF 62/206 reads (30%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.261); catalogued as rs1280904545, COSV99216967; called by muse, mutect2, varscan2
- DTX4 | c.757G>A p.A253T | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs764119701, COSV57088058; called by muse, mutect2, varscan2
- DUS3L | c.1400G>A p.R467H | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs913443761, COSV100288060; called by muse, mutect2, varscan2
- DUSP16 | c.1256G>A p.G419D | Missense Mutation (SNP) | VAF 52/113 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.074); catalogued as COSV99963043; called by muse, mutect2, varscan2
- DUSP2 | c.829C>T p.R277C | Missense Mutation (SNP) | VAF 54/146 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs977626489, COSV99997031; called by muse, mutect2, varscan2
- DUSP22 | c.301G>A p.A101T | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768192099, COSV100740154, COSV60529218; called by muse, mutect2, varscan2
- DYNC1H1 | c.6770A>G p.K2257R | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100794703; called by muse, mutect2, varscan2
- DYNC2I1 | c.1580del p.N527Ifs*23 | Frame Shift Del (DEL) | VAF 22/82 reads (27%) | catalogued as rs751377941; called by mutect2, varscan2
- EBF1 | c.802A>T p.S268C | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.228); catalogued as COSV100565547, COSV100565917; called by muse, mutect2, varscan2
- ECHDC2 | c.232C>T p.R78C | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs781602712, COSV64301283; called by muse, mutect2, varscan2
- EEF1E1 | c.106A>G p.N36D | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.017); catalogued as COSV101121246; called by muse, mutect2, varscan2
- EFTUD2 | c.1846T>C p.S616P | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.112); catalogued as COSV101274529; called by muse, mutect2, varscan2
- EGFR | c.2999C>T p.A1000V | Missense Mutation (SNP) | VAF 9/113 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as COSV51844677; called by muse, mutect2
- EGFR | c.3454G>A p.D1152N | Missense Mutation (SNP) | VAF 42/121 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs368892932, COSV51814970, COSV99294960; called by muse, mutect2, varscan2
- EGR1 | c.1000del p.H334Tfs*198 | Frame Shift Del (DEL) | VAF 10/34 reads (29%) | catalogued as rs746692720; called by mutect2, pindel, varscan2
- EIF2AK1 | c.592del p.I198Sfs*2 | Frame Shift Del (DEL) | VAF 14/44 reads (32%) | catalogued as rs767715156, COSV104389006; called by mutect2, varscan2
- EIF2AK4 | c.281del p.N94Mfs*13 | Frame Shift Del (DEL) | VAF 8/22 reads (36%) | catalogued as COSV55466133; called by pindel, varscan2
- EIF2B3 | c.450del p.A151Qfs*57 | Frame Shift Del (DEL) | VAF 28/81 reads (35%) | catalogued as rs748937918; called by mutect2, varscan2
- ELAVL3 | c.47del p.G16Afs*35 | Frame Shift Del (DEL) | VAF 14/44 reads (32%) | catalogued as rs751148694; called by mutect2, varscan2
- ELF4 | c.1021del p.Q341Rfs*30 | Frame Shift Del (DEL) | VAF 5/34 reads (15%) | catalogued as COSV57452819, COSV57454138; called by mutect2, pindel, varscan2
- ELP1 | c.1670T>C p.I557T | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.342); catalogued as rs762639892, COSV101010364; called by muse, mutect2, varscan2
- EMC1 | c.1462C>A p.L488I | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.033); catalogued as COSV100916433; called by muse, mutect2, varscan2
- EMCN | c.20C>T p.T7I | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV56457287; called by muse, mutect2, varscan2
- ENHO | c.149A>G p.N50S | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.866); catalogued as rs752947654, COSV99646726; called by muse, mutect2, varscan2
- EPB41L2 | c.1559G>A p.R520H | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1382957093, COSV61353484; called by muse, mutect2, varscan2
- EPHA6 | c.2236A>G p.T746A (on ENST00000389672 / NM_001080448.3; = p.T138A on NM_173655.4) | Missense Mutation (SNP) | VAF 10/163 reads (6%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.539); catalogued as COSV101061666; called by muse, mutect2
- EPHX1 | c.335G>T p.R112I | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.026); catalogued as COSV99688829; called by muse, mutect2, varscan2
- EPN2 | c.1289G>A p.G430D | Missense Mutation (SNP) | VAF 32/95 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.674); catalogued as rs1567870283, COSV100127512; called by muse, mutect2, varscan2
- ERF | c.1628T>C p.L543P | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV99724580; called by muse, mutect2, varscan2
- ERN1 | c.2839G>C p.A947P | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.583); catalogued as COSV101458424; called by muse, mutect2, varscan2
- ESYT2 | c.1715A>G p.E572G (on ENST00000613624; = p.E496G on NM_020728.3) | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.506); catalogued as COSV99276460; called by muse, mutect2, varscan2
- EVC | c.2858A>G p.D953G | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV99381501; called by muse, mutect2, varscan2
- EXOC6B | c.1247G>A p.G416D | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55553232; called by muse, mutect2, varscan2
- EZH2 | c.911A>G p.N304S (on ENST00000460911 / NM_001203247.2; = p.N309S on NM_004456.5) | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.132); catalogued as COSV100235289; called by muse, mutect2, varscan2
- FAAP100 | c.2491C>T p.R831C | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as rs772327939, COSV100585301; called by muse, mutect2, varscan2
- FAM131C | c.736C>T p.R246W | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as rs1238560091, COSV100989674; called by muse, mutect2
- FAM193A | c.2017del p.L673Sfs*142 | Frame Shift Del (DEL) | VAF 26/90 reads (29%) | catalogued as COSV61191975; called by mutect2, pindel, varscan2
- FAM43A | c.1216G>A p.G406R | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.078); catalogued as rs986500156, COSV100316419; called by muse, mutect2, varscan2
- FAM83E | c.178A>G p.S60G | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.188); catalogued as rs769111757, COSV99320181; called by muse, mutect2, varscan2
- FAM98A | c.522del p.K174Nfs*2 | Frame Shift Del (DEL) | VAF 14/78 reads (18%) | catalogued as rs1237814873; called by mutect2, varscan2
- FASN | c.6110C>T p.A2037V | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV60754003; called by muse, mutect2, varscan2
- FAT1 | c.3853G>A p.A1285T | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV101499240; called by muse, mutect2, varscan2
- FAT2 | c.9794G>A p.R3265H | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.948); catalogued as COSV55831099; called by muse, mutect2, varscan2
- FAT2 | c.5570A>G p.Q1857R | Missense Mutation (SNP) | VAF 29/110 reads (26%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV99942293; called by muse, mutect2, varscan2
- FAT4 | c.5092C>T p.R1698W | Missense Mutation (SNP) | VAF 35/110 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs755643759, COSV67882388; called by muse, mutect2, varscan2
- FBN2 | c.1969A>G p.T657A | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.13); catalogued as COSV52509441; called by muse, mutect2, varscan2
- FBXL7 | c.1235G>T p.C412F | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100309469; called by muse, mutect2, varscan2
- FCHSD2 | c.2101A>G p.R701G | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as rs1360601398, COSV60809151; called by muse, mutect2, varscan2
- FETUB | c.437del p.K146Rfs*4 | Frame Shift Del (DEL) | VAF 8/41 reads (20%) | catalogued as rs748969702; called by mutect2, varscan2
- FGD6 | c.2420G>A p.G807E | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as COSV100676474; called by muse, mutect2
- FGF23 | c.119T>C p.I40T | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.83); PolyPhen benign (0.003); catalogued as COSV99426351; called by muse, mutect2
- FGFBP1 | c.78del p.V27* | Frame Shift Del (DEL) | VAF 22/69 reads (32%) | catalogued as rs144178676; called by mutect2, varscan2
- FH | c.359T>A p.I120K | Missense Mutation (SNP) | VAF 35/136 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100845003; called by muse, mutect2, varscan2
- FIP1L1 | c.782C>A p.P261H | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.921); catalogued as COSV60996154; called by muse, mutect2, varscan2
- FLG | c.1487A>G p.H496R | Missense Mutation (SNP) | VAF 8/85 reads (9%) | SIFT tolerated (0.72); PolyPhen benign (0.05); catalogued as COSV64235521, COSV64235730; called by muse, mutect2
- FLRT1 | c.445C>T p.R149C | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as rs774763930, COSV55359339; called by muse, mutect2, varscan2
- FOXC1 | c.253G>A p.A85T | Missense Mutation (SNP) | VAF 6/116 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as CM073073, COSV66515893; called by muse, mutect2
- FOXD2 | c.746C>T p.A249V | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.448); catalogued as rs750803367, COSV100599203; called by muse, varscan2
- FOXK2 | c.1278A>G p.P426= | Splice Region (SNP) | VAF 6/18 reads (33%) | catalogued as rs1180214440, COSV100081949; called by muse, mutect2, varscan2
- FOXP4 | c.511-1G>T p.X171_splice | Splice Site (SNP) | VAF 6/63 reads (10%) | catalogued as COSV100332566; called by muse, mutect2
- FRMD3 | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.027); catalogued as rs1278554883, COSV58460424; called by muse, mutect2, varscan2
- FRY | c.1205T>C p.V402A | Missense Mutation (SNP) | VAF 41/110 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as COSV100969006; called by muse, mutect2, varscan2
- FURIN | c.584G>A p.G195D | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866803845, COSV99184645; called by muse, mutect2, varscan2
- FYB1 | c.1100A>G p.D367G | Missense Mutation (SNP) | VAF 64/234 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.877); catalogued as COSV60945469; called by muse, mutect2, varscan2
- GABBR2 | c.1142G>A p.R381Q | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.014); catalogued as rs1008758499, COSV52296246; called by muse, mutect2, varscan2
- GABRR2 | c.1193T>C p.L398P | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV101298900; called by muse, mutect2, varscan2
- GANAB | c.2806G>A p.A936T | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.011); catalogued as rs371161821; called by muse, mutect2, varscan2
- GCNA | c.1760G>A p.R587Q | Missense Mutation (SNP) | VAF 37/112 reads (33%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.827); catalogued as rs754484042, COSV65461912; called by muse, varscan2
- GH2 | c.295C>A p.L99I | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as COSV100236925; called by muse, mutect2, varscan2
- GJA9 | c.554C>T p.P185L | Missense Mutation (SNP) | VAF 40/159 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs144059875, COSV100668065; called by muse, mutect2, varscan2
- GLI3 | c.2906C>G p.A969G | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV101229797; called by muse, mutect2, varscan2
- GLUD2 | c.1096C>A p.P366T | Missense Mutation (SNP) | VAF 33/159 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as COSV100046701; called by muse, mutect2, varscan2
- GNAO1 | c.209A>C p.K70T | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.888); catalogued as COSV99340935; called by muse, mutect2, varscan2
- GNB1L | c.737G>A p.R246H | Missense Mutation (SNP) | VAF 38/99 reads (38%) | SIFT tolerated (0.59); PolyPhen benign (0.018); catalogued as rs371832244; called by muse, mutect2, varscan2
- GNRH2 | c.52C>T p.L18F | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs562403614, COSV99848627; called by muse, mutect2, varscan2
- GOLGA2 | c.1868T>C p.V623A | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as COSV100359755; called by muse, mutect2, varscan2
- GOLGA4 | c.5512G>A p.V1838I | Missense Mutation (SNP) | VAF 58/203 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.228); catalogued as rs749363115, COSV62711806; called by muse, mutect2, varscan2
- GON4L | c.2401A>C p.S801R | Missense Mutation (SNP) | VAF 40/141 reads (28%) | SIFT tolerated (0.97); PolyPhen benign (0.003); catalogued as COSV55192762; called by muse, mutect2, varscan2
- GOT1L1 | c.870del p.N291Tfs*24 | Frame Shift Del (DEL) | VAF 13/58 reads (22%) | catalogued as rs768946390; called by mutect2, pindel, varscan2
- GP2 | c.685T>G p.C229G (on ENST00000381362 / NM_001007240.3; = p.C226G on NM_001502.4) | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56893701; called by muse, mutect2, varscan2
- GPATCH3 | c.1222C>T p.R408C | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs748609259, COSV100658745; called by muse, mutect2, varscan2
- GPC6 | c.1577A>C p.E526A | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.65); PolyPhen benign (0.007); catalogued as COSV100988339; called by muse, mutect2
- GPS2 | c.880C>T p.Q294* | Nonsense Mutation (SNP) | VAF 8/22 reads (36%) | catalogued as COSV100222851; called by muse, mutect2, varscan2
- GPS2 | c.756G>C p.L252F | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV100222852; called by muse, varscan2
- GPT | c.1419del p.L474Wfs*11 | Frame Shift Del (DEL) | VAF 17/72 reads (24%) | catalogued as COSV52953289; called by mutect2, pindel, varscan2
- GRID2 | c.1315C>T p.R439C | Missense Mutation (SNP) | VAF 46/150 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs200889267, COSV56185846, COSV56207492; called by muse, mutect2, varscan2
- GRIK5 | c.1288C>T p.R430C | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.953); catalogued as rs1190385953, COSV99490326; called by muse, mutect2, varscan2
- GRIN3A | c.332G>A p.R111H | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.183); catalogued as rs898383353, COSV100701433; called by muse, mutect2, varscan2
- GRIN3B | c.1543G>A p.G515S | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375104717; called by muse, mutect2, varscan2
- GRIP1 | c.502G>T p.G168W | Missense Mutation (SNP) | VAF 36/65 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99668888; called by muse, mutect2, varscan2
- GRM3 | c.1078C>A p.Q360K | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100862379, COSV64468189; called by muse, mutect2, varscan2
- GRM5 | c.2506G>A p.A836T | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.99); catalogued as rs1254022905, COSV59588107; called by muse, mutect2, varscan2
- GRM7 | c.401T>G p.V134G | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.995); catalogued as COSV100736065; called by muse, mutect2, varscan2
- GSDMA | c.313G>A p.A105T | Missense Mutation (SNP) | VAF 6/126 reads (5%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.842); catalogued as COSV56974283; called by muse, mutect2
- GTF3C1 | c.4398G>T p.K1466N | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.625); catalogued as COSV100649199; called by muse, mutect2, varscan2
- GTF3C1 | c.2299del p.S767Vfs*7 | Frame Shift Del (DEL) | VAF 17/100 reads (17%) | catalogued as rs1231771183; called by mutect2, pindel, varscan2
- GUF1 | c.1934del p.K645Sfs*2 | Frame Shift Del (DEL) | VAF 70/217 reads (32%) | catalogued as COSV54945907; called by mutect2, varscan2
- H3C11 | c.7C>T p.R3* | Nonsense Mutation (SNP) | VAF 12/37 reads (32%) | catalogued as rs745307657, COSV100137811, COSV100138181; called by muse, mutect2, varscan2
- HADH | c.863A>G p.Q288R | Missense Mutation (SNP) | VAF 37/134 reads (28%) | SIFT tolerated (0.3); PolyPhen benign (0.009); catalogued as COSV100531266; called by muse, mutect2, varscan2
- HAP1 | c.932G>A p.C311Y | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.991); catalogued as COSV100169558; called by muse, mutect2, varscan2
- HBD | c.142G>A p.D48N | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV53082140, COSV99496475; called by muse, mutect2, varscan2
- HDAC8 | c.67G>T p.E23* | Nonsense Mutation (SNP) | VAF 17/77 reads (22%) | catalogued as COSV101002357, COSV65227969; called by muse, mutect2, varscan2
- HDGFL2 | c.1865G>A p.G622D | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.1); catalogued as COSV100012181, COSV56684873; called by muse, mutect2, varscan2
- HDHD3 | c.331T>C p.W111R | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99444862; called by muse, mutect2, varscan2
- HECTD1 | c.5053G>A p.D1685N | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.956); catalogued as COSV101237340; called by muse, mutect2, varscan2
- HEG1 | c.2261C>T p.P754L | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); catalogued as rs912548318, COSV100230313; called by muse, mutect2, varscan2
- HERC1 | c.7746A>T p.R2582S | Missense Mutation (SNP) | VAF 44/157 reads (28%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.558); catalogued as COSV101496479; called by muse, mutect2, varscan2
- HERC1 | c.3563A>G p.Q1188R | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV101496480; called by muse, mutect2, varscan2
- HERC2 | c.541del p.S181Vfs*85 | Frame Shift Del (DEL) | VAF 25/105 reads (24%) | catalogued as rs1449081007; called by mutect2, pindel, varscan2
- HEXIM2 | c.274C>T p.R92C | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs368642121; called by muse, mutect2, varscan2
- HHIP | c.40G>A p.V14M | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.003); catalogued as rs766969894, COSV99666959; called by muse, mutect2, varscan2
- HHIPL1 | c.1177G>A p.V393M | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs984397080, COSV100415065; called by muse, mutect2
- HHLA2 | c.311C>T p.A104V | Missense Mutation (SNP) | VAF 38/128 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as rs771206254, COSV63315976; called by muse, mutect2, varscan2
- HIP1R | c.2536_2538del p.K846del | In Frame Del (DEL) | VAF 7/35 reads (20%) | catalogued as rs751385565; called by mutect2, pindel, varscan2
- HMCES | c.1048C>T p.R350C | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.53); catalogued as rs369963919, COSV101077279; called by muse, mutect2
- HOXC9 | c.271C>T p.R91C | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1298707490, COSV57716621; called by muse, mutect2, varscan2
- HRH4 | c.571G>A p.A191T | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT tolerated (0.93); PolyPhen benign (0.136); catalogued as rs773632780, COSV56927767; called by muse, mutect2, varscan2
- HS3ST2 | c.355A>G p.I119V | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.255); catalogued as COSV99757854; called by muse, mutect2, varscan2
- HSD17B10 | c.299C>T p.T100M | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV51447934; called by muse, mutect2, varscan2
- HSPA1L | c.94G>A p.A32T | Missense Mutation (SNP) | VAF 60/217 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.996); catalogued as rs745365008, COSV100989365; called by muse, mutect2, varscan2
- HSPA8 | c.1941A>T p.*647Yext*5 | Nonstop Mutation (SNP) | VAF 8/32 reads (25%) | catalogued as COSV99914307; called by muse, mutect2, varscan2
- HYAL1 | c.655G>A p.G219S | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781935297, COSV99807559; called by muse, mutect2, varscan2
- IGHE | c.292G>A p.D98N | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as rs782517271; called by muse, mutect2, varscan2
- IGLV1-50 | c.275C>T p.A92V | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.537); catalogued as rs775889930; called by muse, mutect2, varscan2
- IGSF21 | c.229G>A p.A77T | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.989); catalogued as rs1361344677, COSV99244351; called by muse, mutect2, varscan2
- IL11 | c.540dup p.L181Afs*6 | Frame Shift Ins (INS) | VAF 34/90 reads (38%) | catalogued as rs768878885; called by mutect2, varscan2
- IL18RAP | c.1688del p.N563Tfs*68 | Frame Shift Del (DEL) | VAF 26/161 reads (16%) | catalogued as COSV99962098; called by mutect2, pindel, varscan2
- IL1RL2 | c.929A>G p.Y310C | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99960467; called by muse, mutect2, varscan2
- IL20 | c.517G>T p.E173* | Nonsense Mutation (SNP) | VAF 3/38 reads (8%) | catalogued as COSV65585302; called by muse, mutect2
- IMPA1 | c.782G>T p.R261M | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV56270447, COSV99808873; called by muse, mutect2, varscan2
- INA | c.613G>T p.G205C | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV100878601; called by muse, mutect2, varscan2
- INPP5F | c.259A>G p.T87A | Missense Mutation (SNP) | VAF 32/119 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.415); catalogued as COSV100740065; called by muse, mutect2, varscan2
- INPPL1 | c.3467G>A p.R1156Q | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.089); catalogued as rs773081790, COSV53356328, COSV99996061; called by muse, mutect2, varscan2
- IPO7 | c.1777C>A p.Q593K | Missense Mutation (SNP) | VAF 26/106 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.313); catalogued as COSV100797805; called by muse, mutect2, varscan2
- IRX3 | c.725del p.G242Afs*18 | Frame Shift Del (DEL) | VAF 11/45 reads (24%) | catalogued as COSV61667883; called by mutect2, pindel, varscan2
- ISG20 | c.182C>A p.P61H | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.222); catalogued as rs371941091; called by muse, mutect2, varscan2
- ISM2 | c.1651G>A p.A551T | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.83); catalogued as rs1392657363, COSV99376547; called by muse, mutect2, varscan2
- ISYNA1 | c.829A>G p.N277D | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99526019; called by muse, mutect2, varscan2
- ITGA10 | c.1633del p.Q545Rfs*15 | Frame Shift Del (DEL) | VAF 18/44 reads (41%) | catalogued as rs781882827; called by mutect2, varscan2
- ITGA11 | c.1538G>A p.G513D | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100241274; called by muse, mutect2, varscan2
- ITGA6 | c.681del p.F227Lfs*3 | Frame Shift Del (DEL) | VAF 21/87 reads (24%) | catalogued as COSV99905555; called by mutect2, pindel, varscan2
- ITGB4 | c.2667G>T p.M889I | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0.013); catalogued as COSV99563788; called by muse, mutect2, varscan2
- ITPR3 | c.6227G>A p.R2076H | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.226); catalogued as rs1047587727, COSV65410562; called by muse, mutect2, varscan2
- ITSN2 | c.4679-2A>G p.X1560_splice | Splice Site (SNP) | VAF 9/50 reads (18%) | catalogued as COSV100743117; called by muse, mutect2, varscan2
- JAG2 | c.2220del p.G741Afs*21 | Frame Shift Del (DEL) | VAF 24/95 reads (25%) | catalogued as rs1555369773; called by mutect2, varscan2
- JAM3 | c.167C>T p.T56M | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.118); catalogued as rs1307104189, COSV54452091; called by muse, mutect2, varscan2
- JMJD1C | c.4841A>T p.N1614I | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as COSV100550363; called by muse, mutect2, varscan2
- KANSL2 | c.896G>A p.S299N | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT tolerated (0.29); PolyPhen benign (0.326); catalogued as COSV63479482; called by muse, mutect2, varscan2
- KBTBD12 | c.1438T>C p.Y480H | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.832); catalogued as COSV59679092; called by muse, mutect2, varscan2
- KBTBD7 | c.1066T>G p.F356V | Missense Mutation (SNP) | VAF 39/141 reads (28%) | SIFT tolerated (0.49); PolyPhen benign (0.341); catalogued as COSV101068071; called by muse, mutect2, varscan2
- KCNAB1 | c.425A>G p.Y142C (on ENST00000490337 / NM_172160.3; = p.Y131C on NM_003471.3) | Missense Mutation (SNP) | VAF 5/85 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1166159900, COSV100204091; called by muse, mutect2
- KCNB2 | c.910C>T p.R304* | Nonsense Mutation (SNP) | VAF 23/72 reads (32%) | catalogued as rs200347487, COSV73051536; called by muse, mutect2, varscan2
- KCNH3 | c.1954C>T p.R652W | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); catalogued as rs1233102533, COSV57791866; called by muse, mutect2, varscan2
- KCNK12 | c.530G>A p.R177H | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV59945108; called by muse, mutect2, varscan2
- KCNS3 | c.1033G>A p.V345M | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as rs143152428, COSV100411133; called by muse, mutect2, varscan2
- KCNT2 | c.2136A>C p.K712N | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.025); catalogued as COSV99652693; called by muse, varscan2
- KCNT2 | c.2108G>A p.C703Y | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99652699; called by muse, varscan2
- KCTD10 | c.838G>A p.G280R | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as rs1279950591, COSV99949167; called by muse, mutect2, varscan2
- KCTD15 | c.247A>C p.S83R | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.044); catalogued as COSV99393110; called by muse, mutect2, varscan2
- KCTD19 | c.721A>G p.I241V | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.014); catalogued as rs1401191578, COSV100430814; called by muse, mutect2, varscan2
- KDM3A | c.863C>A p.P288H | Missense Mutation (SNP) | VAF 33/114 reads (29%) | SIFT tolerated (0.33); PolyPhen benign (0.014); catalogued as COSV57220679, COSV57225597; called by muse, mutect2, varscan2
- KDM4A | c.157T>G p.W53G | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.462); catalogued as COSV100969435; called by muse, mutect2, varscan2
- KDM4B | c.1559C>G p.A520G | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.35); PolyPhen benign (0.047); catalogued as COSV99346060; called by muse, varscan2
- KDM5A | c.3278T>C p.V1093A | Missense Mutation (SNP) | VAF 31/160 reads (19%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV101238713; called by muse, mutect2, varscan2
- KDM5B | c.1832G>A p.G611D | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99350358; called by muse, mutect2, varscan2
- KDM6A | c.3472A>C p.N1158H | Missense Mutation (SNP) | VAF 37/163 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65044582; called by muse, mutect2, varscan2
- KDM6B | c.3278G>A p.R1093H | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.818); catalogued as rs202119281, COSV99641070; called by muse, mutect2, varscan2
- KIAA1109 | c.8705C>A p.P2902H | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52669336, COSV99151272; called by muse, mutect2
- KIAA1328 | c.935C>T p.A312V | Missense Mutation (SNP) | VAF 29/103 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.069); catalogued as COSV99693840; called by muse, mutect2, varscan2
- KIAA1549 | c.5716C>A p.P1906T (on ENST00000422774 / NM_001164665.2; = p.P1890T on NM_020910.3) | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.122); catalogued as COSV54317086; called by muse, mutect2
- KIAA1841 | c.500A>T p.D167V | Missense Mutation (SNP) | VAF 48/165 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs756138624, COSV99693514; called by muse, mutect2, varscan2
- KIF18A | c.2491C>T p.R831W | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as rs142577501; called by muse, mutect2, varscan2
- KIF19 | c.1748C>T p.A583V | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.033); catalogued as COSV100739020; called by muse, mutect2, varscan2
- KIF26A | c.278C>T p.T93I | Missense Mutation (SNP) | VAF 50/149 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100180997; called by muse, mutect2, varscan2
- KIF26B | c.188T>G p.L63R | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.641); catalogued as COSV69460731; called by muse, mutect2, varscan2
- KIF4A | c.3170A>G p.D1057G | Missense Mutation (SNP) | VAF 12/332 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.036); catalogued as COSV100979470; called by muse, mutect2
- KIFC3 | c.878T>G p.L293R | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.869); catalogued as rs1043890633, COSV101109144, COSV65550625; called by muse, mutect2
- KIT | c.2206G>A p.A736T | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.6); PolyPhen benign (0.036); catalogued as COSV99853763; called by muse, mutect2, varscan2
- KLF14 | c.947C>T p.A316V | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.003); catalogued as rs782076927, COSV100205869; called by muse, mutect2, varscan2
- KLHDC4 | c.581G>T p.G194V | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99566251; called by muse, mutect2, varscan2
- KLHDC7B | c.1552T>C p.W518R (on ENST00000395676; = p.W1159R on NM_138433.5) | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV101192910; called by muse, mutect2, varscan2
- KLRK1 | c.164del p.F55Sfs*7 | Frame Shift Del (DEL) | VAF 38/148 reads (26%) | catalogued as rs756606329, COSV53699502; called by mutect2, varscan2
- KMT2D | c.4843C>T p.R1615* | Nonsense Mutation (SNP) | VAF 46/91 reads (51%) | catalogued as CM105487, COSV56420226; called by muse, mutect2, varscan2
- KNDC1 | c.2401C>T p.P801S | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs1284149495, COSV100464175; called by muse, mutect2
- KNSTRN | c.706G>A p.A236T | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.3); PolyPhen benign (0.297); catalogued as COSV51104998; called by muse, mutect2, varscan2
- KRBA1 | c.1714C>T p.Q572* | Nonsense Mutation (SNP) | VAF 18/73 reads (25%) | catalogued as COSV99752442; called by muse, mutect2, varscan2
- KRT10 | c.1321C>T p.R441* | Nonsense Mutation (SNP) | VAF 32/140 reads (23%) | catalogued as COSV99509996; called by muse, varscan2
- KRT13 | c.388G>A p.A130T | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.73); PolyPhen benign (0.053); catalogued as rs1047174279, COSV55840342; called by muse, mutect2, varscan2
- KRT6A | c.1278G>T p.K426N | Missense Mutation (SNP) | VAF 6/148 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100416865; called by muse, mutect2
- KRT6A | c.43C>A p.R15S | Missense Mutation (SNP) | VAF 72/150 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV100416866; called by muse, varscan2
- KRT71 | c.80del p.G27Afs*111 | Frame Shift Del (DEL) | VAF 18/75 reads (24%) | catalogued as rs764884198; called by mutect2, pindel, varscan2
- KRT80 | c.950A>G p.K317R | Missense Mutation (SNP) | VAF 22/39 reads (56%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.953); catalogued as COSV57548775; called by muse, mutect2, varscan2
- KRT84 | c.947C>T p.T316M | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs370280302; called by muse, mutect2, varscan2
- L1CAM | c.749G>A p.S250N | Missense Mutation (SNP) | VAF 44/173 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100648987; called by muse, mutect2, varscan2
- LAD1 | c.763C>A p.L255M | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.203); catalogued as COSV100943816; called by muse, mutect2, varscan2
- LAMA2 | c.97G>A p.A33T | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs1362087620, COSV101370311; called by muse, mutect2, varscan2
- LAMC3 | c.2996A>T p.D999V | Missense Mutation (SNP) | VAF 37/124 reads (30%) | SIFT tolerated (0.32); PolyPhen benign (0.038); catalogued as COSV100735933; called by muse, mutect2, varscan2
- LANCL2 | c.227G>A p.R76Q | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs759332300, COSV54650887; called by muse, mutect2, varscan2
- LANCL3 | c.656C>T p.P219L | Missense Mutation (SNP) | VAF 47/188 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0.026); catalogued as COSV101065561; called by muse, mutect2, varscan2
- LARGE1 | c.1549G>A p.A517T | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.313); catalogued as rs148771159; called by muse, mutect2, varscan2
- LARP1 | c.2027C>A p.A676D (on ENST00000518297 / NM_033551.3; = p.A599D on NM_015315.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.597); catalogued as COSV100303661; called by muse, mutect2, varscan2
- LGI1 | c.637A>G p.S213G | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.065); catalogued as COSV101004383; called by muse, mutect2, varscan2
- LHFPL5 | c.16C>T p.P6S | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.021); catalogued as COSV100798951; called by muse, mutect2, varscan2
- LHX9 | c.1103C>A p.P368H | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100435758; called by muse, mutect2, varscan2
- LINS1 | c.2263A>G p.N755D | Missense Mutation (SNP) | VAF 34/129 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV100130128; called by muse, mutect2, varscan2
- LLGL2 | c.658G>A p.G220S | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.96); PolyPhen benign (0.001); catalogued as COSV99389398; called by muse, mutect2, varscan2
- LMTK2 | c.1257G>T p.E419D | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.474); catalogued as COSV51999268; called by muse, mutect2, varscan2
- LRCH2 | c.1904T>C p.M635T | Missense Mutation (SNP) | VAF 52/153 reads (34%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.584); catalogued as COSV57749635; called by muse, mutect2, varscan2
- LRP1B | c.5117A>G p.K1706R | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV67290885; called by muse, mutect2, varscan2
- LRP3 | c.922G>A p.V308M | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs762589974, COSV99472121; called by muse, mutect2, varscan2
- LRRCC1 | c.1721C>T p.A574V | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs765839225, COSV64482561; called by muse, mutect2, varscan2
- LRRIQ1 | c.3451C>A p.R1151S | Missense Mutation (SNP) | VAF 36/66 reads (55%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV101279927, COSV67832844; called by muse, mutect2, varscan2
- LRRN3 | c.615C>A p.D205E | Missense Mutation (SNP) | VAF 42/143 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.045); catalogued as COSV57825074; called by muse, mutect2, varscan2
- LSM11 | c.589-1G>A p.X197_splice | Splice Site (SNP) | VAF 24/64 reads (38%) | catalogued as COSV53848099; called by muse, varscan2
- LSMEM2 | c.205G>A p.A69T | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV100269393; called by muse, mutect2, varscan2
- LTBP4 | c.758C>G p.A253G (on ENST00000308370 / NM_001042544.1; = p.A216G on NM_003573.2) | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV99183811; called by muse, mutect2
- MAGEC1 | c.2747C>T p.A916V | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs776851614, COSV53578740; called by muse, mutect2, varscan2
- MAGEE1 | c.343T>C p.S115P | Missense Mutation (SNP) | VAF 41/105 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as COSV100819348; called by muse, mutect2, varscan2
- MANF | c.334_336del p.K112del | In Frame Del (DEL) | VAF 14/69 reads (20%) | catalogued as rs782449001; called by pindel, varscan2
- MAP1B | c.5561C>A p.P1854H | Missense Mutation (SNP) | VAF 7/103 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.054); catalogued as COSV99702108; called by muse, mutect2
- MAP1S | c.1910G>A p.R637H | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs774928303, COSV60722011; called by muse, mutect2, varscan2
- MAP3K10 | c.1012G>T p.E338* | Nonsense Mutation (SNP) | VAF 5/25 reads (20%) | catalogued as COSV99454192; called by muse, mutect2
- MARK4 | c.22G>T p.A8S | Missense Mutation (SNP) | VAF 39/138 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV99488146; called by muse, varscan2
- MAST1 | c.1346T>C p.M449T | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV52251540, COSV99262654; called by muse, mutect2, varscan2
- MAST4 | c.3133C>T p.R1045* (on ENST00000403625 / NM_001164664.2; = p.R856* on NM_015183.3) | Nonsense Mutation (SNP) | VAF 43/117 reads (37%) | catalogued as rs367575904, COSV55146202; called by muse, mutect2, varscan2
- MAST4 | c.6812C>T p.P2271L (on ENST00000403625 / NM_001164664.2; = p.P2082L on NM_015183.3) | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.007); catalogued as rs1223754877, COSV99843621; called by muse, mutect2, varscan2
- MAZ | c.39del p.F14Sfs*15 | Frame Shift Del (DEL) | VAF 24/64 reads (38%) | catalogued as rs767720617; called by mutect2, varscan2
- MBD5 | c.2656G>T p.G886W | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV101290017; called by muse, mutect2, varscan2
- MBTPS1 | c.310A>G p.I104V | Missense Mutation (SNP) | VAF 34/117 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100597475; called by muse, mutect2, varscan2
- MCOLN2 | c.178C>T p.R60C | Missense Mutation (SNP) | VAF 30/103 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.425); catalogued as rs201171839, COSV52295381; called by muse, mutect2, varscan2
- MDGA2 | c.1206del p.G403Dfs*22 (on ENST00000399232 / NM_001113498.2; = p.G105Dfs*22 on NM_182830.4) | Frame Shift Del (DEL) | VAF 27/123 reads (22%) | catalogued as rs1180255648; called by mutect2, pindel, varscan2
- MDN1 | c.5966del p.K1989Rfs*65 | Frame Shift Del (DEL) | VAF 12/46 reads (26%) | catalogued as rs750092100; called by mutect2, varscan2
- ME2 | c.1222G>A p.A408T | Missense Mutation (SNP) | VAF 9/198 reads (5%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.555); catalogued as COSV100360712; called by muse, mutect2
- METTL2B | c.164A>G p.Q55R | Missense Mutation (SNP) | VAF 38/119 reads (32%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs767735930, COSV52308784; called by muse, mutect2, varscan2
- MFN2 | c.86T>C p.L29P | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99336649; called by muse, mutect2
- MFSD10 | c.28A>G p.T10A | Missense Mutation (SNP) | VAF 35/107 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.023); catalogued as COSV99296272; called by muse, mutect2, varscan2
- MFSD14A | c.806T>A p.L269* | Nonsense Mutation (SNP) | VAF 61/185 reads (33%) | catalogued as rs749059126, COSV100924604, COSV64514301; called by muse, mutect2, varscan2
- MGAM | c.4295T>C p.V1432A | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.063); catalogued as COSV101527435; called by mutect2, varscan2
- MGST2 | c.309del p.K103Nfs*8 | Frame Shift Del (DEL) | VAF 12/57 reads (21%) | catalogued as COSV55498546; called by mutect2, pindel, varscan2
- MIA2 | c.89T>A p.M30K | Missense Mutation (SNP) | VAF 26/116 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.216); catalogued as COSV54492331; called by muse, mutect2, varscan2
- MICAL3 | c.4495del p.R1499Gfs*106 | Frame Shift Del (DEL) | VAF 11/34 reads (32%) | catalogued as rs765803753; called by mutect2, pindel, varscan2
- MINAR1 | c.2104del p.S702Afs*11 | Frame Shift Del (DEL) | VAF 20/68 reads (29%) | catalogued as rs748072217, COSV59581461; called by mutect2, varscan2
- MKI67 | c.5350A>G p.T1784A | Missense Mutation (SNP) | VAF 29/111 reads (26%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.672); catalogued as COSV100896380; called by muse, mutect2, varscan2
- MLH3 | c.1755del p.E586Nfs*24 | Frame Shift Del (DEL) | VAF 35/108 reads (32%) | catalogued as rs751465048; called by mutect2, varscan2
- MLYCD | c.1178C>T p.A393V | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.69); PolyPhen benign (0.007); catalogued as rs200750439, COSV52305058; called by muse, mutect2, varscan2
- MMGT1 | c.389G>A p.R130H | Missense Mutation (SNP) | VAF 58/208 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs782610277, COSV100018457; called by muse, mutect2, varscan2
- MMP15 | c.1267T>C p.Y423H | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99539372; called by muse, mutect2, varscan2
- MOBP | c.176A>G p.D59G | Missense Mutation (SNP) | VAF 19/74 reads (26%) | PolyPhen benign (0.301); catalogued as COSV100215497, COSV60654189; called by muse, mutect2, varscan2
- MOCS3 | c.868C>A p.L290M | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99724218; called by muse, mutect2, varscan2
- MOGS | c.881del p.P294Lfs*11 | Frame Shift Del (DEL) | VAF 9/42 reads (21%) | catalogued as rs750486813; called by mutect2, varscan2
- MOV10L1 | c.1594_1596del p.E532del | In Frame Del (DEL) | VAF 38/107 reads (36%) | catalogued as rs759340800; called by mutect2, pindel, varscan2
- MPZL1 | c.364A>G p.I122V | Missense Mutation (SNP) | VAF 65/155 reads (42%) | SIFT tolerated (0.23); PolyPhen benign (0.426); catalogued as COSV100850335; called by muse, mutect2, varscan2
- MRGPRF | c.464G>T p.R155L | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs767308722, COSV100307811, COSV57995584; called by muse, mutect2, varscan2
- MROH1 | c.1487G>A p.R496H | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.395); catalogued as rs1433381128; called by muse, mutect2, varscan2
- MRPL47 | c.362G>A p.R121Q | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.314); catalogued as rs917879069, COSV52022965; called by muse, mutect2, varscan2
- MRTFA | c.1220del p.P407Qfs*30 | Frame Shift Del (DEL) | VAF 12/40 reads (30%) | catalogued as rs34028511; called by mutect2, pindel, varscan2
- MTMR4 | c.1371A>C p.Q457H | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.921); catalogued as COSV100050932; called by muse, mutect2, varscan2
- MTO1 | c.1948T>C p.S650P (on ENST00000370300 / NM_133645.3; = p.S625P on NM_012123.4) | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.722); catalogued as COSV100940385; called by muse, mutect2
- MUC2 | c.863C>T p.T288M | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0.01); catalogued as rs746895360; called by muse, mutect2, varscan2
- MUC4 | c.814T>A p.S272T | Missense Mutation (SNP) | VAF 46/163 reads (28%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.159); catalogued as rs1332527405, COSV100640227; called by muse, mutect2, varscan2
- MYBBP1A | c.179A>G p.Y60C | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV99625745; called by muse, mutect2, varscan2
- MYH1 | c.4014G>C p.Q1338H | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV99875424; called by muse, mutect2
- MYH14 | c.4271G>A p.R1424H | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as rs1303854176, COSV51811684, COSV51823337; called by muse, mutect2, varscan2
- MYH3 | c.5286C>T p.D1762= | Splice Region (SNP) | VAF 21/67 reads (31%) | catalogued as rs552501098, COSV99878006; called by muse, mutect2, varscan2
- MYH8 | c.4958T>C p.L1653P | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as COSV101238348; called by muse, mutect2, varscan2
- MYH9 | c.3110G>A p.R1037H | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.629); catalogued as rs1194942976, COSV53384546; called by muse, mutect2
- MYO16 | c.2525del p.F842Sfs*17 | Frame Shift Del (DEL) | VAF 10/50 reads (20%) | catalogued as rs761471964; called by mutect2, varscan2
- MYO3A | c.2483G>T p.G828V | Missense Mutation (SNP) | VAF 63/196 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56325791, COSV99779094; called by muse, mutect2, varscan2
- MYO5A | c.1841G>A p.R614Q | Missense Mutation (SNP) | VAF 29/117 reads (25%) | SIFT tolerated (0.49); PolyPhen benign (0.322); catalogued as rs751663129, COSV100697518; called by muse, mutect2, varscan2
- MYO7B | c.5132A>G p.Y1711C | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101268029; called by muse, mutect2, varscan2
- MYT1 | c.1867G>A p.A623T | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.49); catalogued as rs1434571886, COSV60509297; called by muse, mutect2
- MZF1 | c.1768G>A p.V590I | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT tolerated (0.76); PolyPhen benign (0.172); catalogued as rs536663646, COSV99285135; called by muse, mutect2, varscan2
- N4BP2L2 | c.1973del p.N658Ifs*14 (on ENST00000674422; = p.N229Ifs*14 on NM_033111.4) | Frame Shift Del (DEL) | VAF 36/136 reads (26%) | catalogued as COSV62634500; called by mutect2, pindel, varscan2
- NALCN | c.1144C>T p.R382W | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs867467226, COSV51959339; called by muse, mutect2, varscan2
- NAT16 | c.529A>G p.T177A | Missense Mutation (SNP) | VAF 25/104 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.135); catalogued as COSV100296235; called by muse, mutect2, varscan2
- NAV2 | c.2647G>A p.A883T (on ENST00000396087 / NM_001244963.2; = p.A860T on NM_145117.5) | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.585); catalogued as rs752246924, COSV62322194; called by muse, mutect2, varscan2
- NBPF1 | c.2230G>T p.D744Y | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99844351; called by muse, mutect2, varscan2
- NCAPD3 | c.2581G>T p.G861W | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101599343; called by muse, mutect2, varscan2
- NCKAP1 | c.3098C>T p.A1033V | Missense Mutation (SNP) | VAF 35/102 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as COSV100720116; called by muse, mutect2, varscan2
- NCKAP5L | c.1418G>A p.G473D | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.625); catalogued as COSV100258566; called by muse, mutect2, varscan2
- NCOA1 | c.189A>C p.K63N | Missense Mutation (SNP) | VAF 6/112 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99945677; called by muse, mutect2
- NCOR2 | c.4330C>T p.R1444W | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs766376384, COSV100657118; called by muse, mutect2, varscan2
- NCOR2 | c.3371C>T p.A1124V | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.359); catalogued as COSV62297238; called by muse, mutect2, varscan2
- NDRG3 | c.349G>T p.A117S (on ENST00000349004 / NM_032013.4; = p.A105S on NM_022477.4) | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.178); catalogued as COSV62421788; called by muse, mutect2, varscan2
- NDRG4 | c.298G>T p.V100L (on ENST00000570248 / NM_001378344.1; = p.V132L on NM_020465.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV99261938; called by muse, mutect2, varscan2
- NDUFA9 | c.17A>G p.Q6R | Missense Mutation (SNP) | VAF 45/76 reads (59%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV99865447; called by muse, mutect2, varscan2
- NECTIN1 | c.1226A>G p.H409R | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.326); catalogued as COSV99871955; called by muse, mutect2, varscan2
- NEFM | c.2719G>A p.A907T | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV99647129; called by muse, mutect2
- NES | c.2395C>T p.L799F | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.082); catalogued as COSV100957821; called by muse, mutect2, varscan2
- NETO1 | c.825T>G p.S275R | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.348); catalogued as COSV100198461; called by muse, mutect2, varscan2
- NEURL4 | c.1300G>T p.D434Y | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100224042, COSV59757300; called by muse, mutect2, varscan2
- NFRKB | c.932del p.K311Rfs*13 (on ENST00000446488 / NM_001143835.2; = p.K336Rfs*13 on NM_006165.3) | Frame Shift Del (DEL) | VAF 13/42 reads (31%) | catalogued as rs149369172, COSV58756820; called by mutect2, varscan2
- NLGN1 | c.846C>A p.S282R | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs377341309, COSV100849049; called by muse, mutect2, varscan2
- NLRC5 | c.2635G>T p.G879W | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV99346851; called by muse, mutect2, varscan2
- NLRC5 | c.5027A>G p.D1676G | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.215); catalogued as COSV99346854; called by muse, mutect2, varscan2
- NLRP13 | c.145del p.Q49Rfs*12 | Frame Shift Del (DEL) | VAF 20/74 reads (27%) | catalogued as rs1198298310; called by mutect2, pindel, varscan2
- NLRP9 | c.2806G>C p.A936P | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100242858; called by muse, mutect2, varscan2
- NOD2 | c.1583del p.P528Qfs*235 | Frame Shift Del (DEL) | VAF 12/39 reads (31%) | catalogued as rs754073471; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- NOS2 | c.3365G>A p.R1122H | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs748134272, COSV100569593, COSV100569695; called by muse, mutect2, varscan2
- NPHP3 | c.730G>T p.G244* | Nonsense Mutation (SNP) | VAF 16/46 reads (35%) | catalogued as rs1310366874, COSV100446740; called by muse, mutect2, varscan2
- NPHP4 | c.940T>G p.L314V | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.945); catalogued as COSV100976822; called by muse, mutect2, varscan2
- NPR1 | c.2392C>T p.R798C | Missense Mutation (SNP) | VAF 42/101 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.33); catalogued as rs753081607, COSV64117677; called by muse, mutect2, varscan2
- NR1H2 | c.67G>A p.A23T | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs772224466, COSV53800029; called by muse, mutect2, varscan2
- NR4A1 | c.1042C>T p.R348W | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767305762, COSV54482846; called by muse, mutect2, varscan2
- NRARP | c.305A>G p.Y102C | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100751944; called by muse, mutect2, varscan2
- NRXN2 | c.3991G>A p.V1331M | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.76); catalogued as COSV99633437; called by muse, mutect2, varscan2
- NRXN3 | c.1270C>T p.R424W (on ENST00000335750 / NM_001330195.2; = p.R51W on NM_004796.6) | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs748055286, COSV59755799, COSV59799087; called by muse, mutect2, varscan2
- NSD1 | c.2903A>G p.K968R | Missense Mutation (SNP) | VAF 50/172 reads (29%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.006); catalogued as COSV61771801; called by muse, mutect2, varscan2
- NSUN4 | c.334G>T p.G112C | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.552); catalogued as COSV100197403; called by muse, mutect2
- NUDT19 | c.1085A>G p.H362R | Missense Mutation (SNP) | VAF 38/172 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV67959453; called by muse, mutect2, varscan2
- NUDT3 | c.403G>A p.V135M | Missense Mutation (SNP) | VAF 29/107 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV101466190; called by muse, mutect2, varscan2
- OBSCN | c.13355C>T p.T4452I | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.1); catalogued as COSV99475756; called by muse, mutect2, varscan2
- OBSCN | c.20977del p.A6993Pfs*79 | Frame Shift Del (DEL) | VAF 17/64 reads (27%) | catalogued as rs762005098; called by mutect2, pindel, varscan2
- OBSCN | c.21161C>T p.A7054V | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs1364964677, COSV100802898; called by muse, mutect2, varscan2
- OBSCN | c.21575G>T p.G7192V | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); catalogued as COSV100802900; called by muse, mutect2, varscan2
- ODF3L1 | c.800C>A p.P267Q | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs1250487704, COSV100150746; called by muse, mutect2, varscan2
- OGFOD2 | c.917G>A p.W306* (on ENST00000228922 / NM_001304833.1; = p.W246* on NM_024623.3) | Nonsense Mutation (SNP) | VAF 12/55 reads (22%) | catalogued as COSV99758595; called by muse, mutect2, varscan2
- ONECUT2 | c.605G>A p.R202H | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV101529768; called by muse, mutect2, varscan2
- OPA1 | c.2795T>A p.V932E (on ENST00000361510 / NM_130837.3; = p.V877E on NM_015560.3) | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100655247; called by muse, mutect2, varscan2
- OPLAH | c.1493C>T p.A498V | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.602); catalogued as COSV101470752; called by muse, mutect2, varscan2
- OR10Q1 | c.457C>A p.L153M | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.11); catalogued as rs777748474, COSV100372213; called by muse, mutect2, varscan2
- OR14C36 | c.315del p.F105Lfs*28 | Frame Shift Del (DEL) | VAF 17/67 reads (25%) | catalogued as rs761899382; called by mutect2, varscan2
- OR2V2 | c.718G>A p.A240T | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT tolerated (0.48); PolyPhen benign (0.092); catalogued as COSV100080067; called by muse, mutect2, varscan2
- OR4C11 | c.309T>A p.H103Q | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); catalogued as COSV56353014; called by muse, mutect2, varscan2
- OR4F6 | c.476A>G p.Q159R | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.995); catalogued as COSV61026682; called by muse, mutect2, varscan2
- OR51B5 | c.688G>T p.E230* | Nonsense Mutation (SNP) | VAF 24/72 reads (33%) | catalogued as COSV100332496; called by muse, mutect2, varscan2
- OR52N5 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 31/95 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV100399652; called by muse, mutect2, varscan2
- OR6C75 | c.599del p.L200* | Frame Shift Del (DEL) | VAF 20/117 reads (17%) | catalogued as rs746200712; called by mutect2, varscan2
- OR6T1 | c.191G>A p.R64Q | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT tolerated (0.39); PolyPhen benign (0.015); catalogued as rs375228674; called by muse, mutect2, varscan2
- OSBPL5 | c.1294T>C p.W432R | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99720249; called by muse, mutect2, varscan2
- OTOA | c.1214C>A p.S405* (on ENST00000286149; = p.S391* on NM_144672.4) | Nonsense Mutation (SNP) | VAF 8/49 reads (16%) | catalogued as COSV53750717, COSV99624132; called by muse, mutect2, varscan2
- PACRGL | c.366+2T>C p.X122_splice | Splice Site (SNP) | VAF 13/46 reads (28%) | catalogued as COSV99763990; called by muse, mutect2, varscan2
- PADI6 | c.992C>T p.T331I | Missense Mutation (SNP) | VAF 40/107 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.743); catalogued as rs1300346813, COSV100639918; called by muse, mutect2, varscan2
- PAPOLA | c.2019A>C p.E673D | Missense Mutation (SNP) | VAF 46/224 reads (21%) | SIFT tolerated (0.49); PolyPhen benign (0.037); catalogued as COSV99354103; called by muse, varscan2
- PAQR4 | c.131A>G p.Y44C | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99233977; called by muse, mutect2, varscan2
- PARD3B | c.917T>G p.I306S | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.6); PolyPhen benign (0.018); catalogued as COSV100592933; called by muse, mutect2, varscan2
- PATL1 | c.1663A>G p.M555V | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV100274827; called by muse, mutect2, varscan2
- PC | c.2393C>T p.A798V | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1288223859, COSV100547005; called by muse, varscan2
- PCARE | c.3832C>T p.P1278S | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.124); catalogued as COSV100527454; called by muse, mutect2, varscan2
- PCDH10 | c.3074C>T p.T1025M | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated, low confidence (0.21); PolyPhen possibly damaging (0.548); catalogued as rs747022854, COSV52087382; called by muse, mutect2, varscan2
- PCDH17 | c.1574T>G p.V525G | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100931540; called by muse, mutect2, varscan2
- PCDH8 | c.1954G>A p.E652K | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs767003417, COSV100131408; called by muse, mutect2
- PCDHA5 | c.1540G>A p.G514S | Missense Mutation (SNP) | VAF 7/87 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV65351320; called by muse, mutect2
- PCDHB16 | c.1733G>A p.R578Q | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.142); catalogued as rs781886261, COSV99501667; called by muse, varscan2
- PCDHB3 | c.47T>C p.L16P | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.931); catalogued as rs1554272054, COSV99164747; called by muse, mutect2, varscan2
- PCDHB8 | c.1745A>T p.E582V | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.936); catalogued as COSV99176619; called by muse, mutect2, varscan2
- PCDHGA3 | c.2327C>T p.A776V | Missense Mutation (SNP) | VAF 64/246 reads (26%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.07); catalogued as rs370532251, COSV53990751; called by muse, mutect2, varscan2
- PCDHGB2 | c.892dup p.T298Nfs*9 | Frame Shift Ins (INS) | VAF 19/82 reads (23%) | catalogued as rs758957504; called by mutect2, pindel, varscan2
- PCDHGC3 | c.2066del p.N689Ifs*10 | Frame Shift Del (DEL) | VAF 18/52 reads (35%) | catalogued as rs1156842877; called by mutect2, varscan2
- PCSK4 | c.718A>G p.I240V | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as COSV99278537; called by muse, mutect2, varscan2
- PDE5A | c.1742A>C p.D581A | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.757); catalogued as COSV99308548; called by muse, mutect2, varscan2
- PDE6A | c.2531del p.G844Efs*48 | Frame Shift Del (DEL) | VAF 7/43 reads (16%) | catalogued as rs769569931, COSV54926556; called by mutect2, pindel, varscan2
- PDE8A | c.2194C>T p.R732* | Nonsense Mutation (SNP) | VAF 28/78 reads (36%) | catalogued as rs748220659, COSV59637606; called by muse, mutect2, varscan2
- PDIA4 | c.1819G>T p.A607S (on ENST00000286091 / NM_001371244.1; = p.A606S on NM_004911.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.053); catalogued as COSV99618410; called by muse, mutect2, varscan2
- PDS5A | c.1648G>A p.G550R | Missense Mutation (SNP) | VAF 33/128 reads (26%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.987); catalogued as rs1308211352, COSV100337267; called by muse, varscan2
- PDZD2 | c.308del p.G103Afs*19 | Frame Shift Del (DEL) | VAF 12/62 reads (19%) | catalogued as rs750970663; called by mutect2, pindel, varscan2
- PERP | c.61A>G p.S21G | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.078); catalogued as COSV101408582; called by muse, mutect2, varscan2
- PGR | c.1997G>A p.S666N | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV54799912; called by muse, mutect2, varscan2
- PHF1 | c.1239G>T p.Q413H (on ENST00000374516 / NM_024165.3; = p.A410S on NM_002636.5) | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV99538160; called by muse, mutect2
- PHF19 | c.1130G>T p.G377V | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.31); PolyPhen benign (0.006); catalogued as COSV65878577; called by muse, mutect2, varscan2
- PHKA2 | c.1337C>T p.A446V | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101176896; called by muse, mutect2, varscan2
- PIAS4 | c.233A>G p.H78R | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT tolerated (0.43); PolyPhen benign (0.026); catalogued as COSV53678926; called by muse, mutect2, varscan2
- PITPNM3 | c.2536T>C p.S846P | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.936); catalogued as COSV99338191; called by muse, mutect2, varscan2
- PKD2L1 | c.764del p.G255Afs*64 | Frame Shift Del (DEL) | VAF 5/18 reads (28%) | catalogued as rs1169311338; called by mutect2, pindel, varscan2
- PKHD1 | c.10235T>C p.V3412A | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.058); catalogued as COSV100944126; called by muse, mutect2, varscan2
- PKN1 | c.1522A>T p.M508L | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.661); catalogued as COSV99661067; called by muse, mutect2, varscan2
- PKP4 | c.1018C>T p.R340C | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.591); catalogued as rs371693650, COSV101080622; called by muse, mutect2, varscan2
- PLA2R1 | c.305G>C p.S102T | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV99322618; called by muse, mutect2, varscan2
- PLCH2 | c.2243C>T p.S748L | Missense Mutation (SNP) | VAF 35/87 reads (40%) | SIFT tolerated (0.2); PolyPhen benign (0.024); catalogued as rs56072033; called by muse, mutect2, varscan2
- PLD2 | c.1405C>T p.H469Y | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV54005677; called by muse, mutect2, varscan2
- PLEKHA5 | c.929dup p.N310Kfs*8 | Frame Shift Ins (INS) | VAF 16/86 reads (19%) | catalogued as rs1565550899; called by mutect2, varscan2
- PLEKHF1 | c.703G>A p.A235T | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV101460756; called by muse, mutect2, varscan2
- PLEKHH1 | c.628G>A p.G210S | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.001); catalogued as COSV100232931; called by muse, mutect2, varscan2
- PLXNA1 | c.1526G>A p.R509Q | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0.015); catalogued as rs777812102, COSV99302724; called by muse, mutect2, varscan2
- PLXNA2 | c.5577G>C p.K1859N | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.41); catalogued as COSV100885296; called by muse, mutect2, varscan2
- PLXNA3 | c.70C>T p.R24C | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.505); catalogued as rs782215325, COSV100859888; called by muse, mutect2, varscan2
- PLXND1 | c.5339A>G p.Q1780R | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as COSV100139406; called by muse, mutect2, varscan2
- PNPLA8 | c.560G>A p.R187H | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs780391824, COSV57552512; called by muse, mutect2, varscan2
- POFUT1 | c.1090C>T p.R364W | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1165070275, COSV65338489; called by muse, mutect2, varscan2
- POLD1 | c.2969G>A p.R990H | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs771789997, COSV54530125, COSV99569887; ClinVar: uncertain significance; called by muse, varscan2
- POLE | c.3641A>C p.D1214A | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.928); catalogued as COSV100265939; called by muse, mutect2, varscan2
- POLG2 | c.158A>G p.N53S | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs1555669640, COSV99857812; called by muse, mutect2, varscan2
- POSTN | c.1073T>C p.I358T | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101123297; called by muse, mutect2, varscan2
- PPARGC1A | c.1123C>T p.R375W | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs199772441, COSV53527868; called by muse, mutect2, varscan2
- PPL | c.1968G>A p.A656= | Splice Region (SNP) | VAF 11/35 reads (31%) | catalogued as rs199762487; called by muse, mutect2, varscan2
- PPP1R13B | c.131A>G p.H44R | Missense Mutation (SNP) | VAF 5/70 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV99158216; called by muse, mutect2
- PPP2R3B | c.814G>A p.A272T | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV101065518; called by muse, mutect2, varscan2
- PRDM16 | c.2848C>T p.R950* | Nonsense Mutation (SNP) | VAF 40/125 reads (32%) | catalogued as rs1294136105, COSV54599926; called by muse, mutect2, varscan2
- PRDM2 | c.2675T>C p.L892P | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99341290; called by muse, mutect2, varscan2
- PREPL | c.368A>G p.Y123C | Missense Mutation (SNP) | VAF 115/427 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV53216422; called by muse, mutect2, varscan2
- PRICKLE2 | c.2327G>T p.R776M (on ENST00000295902; = p.R720M on NM_198859.4) | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.234); catalogued as rs1408077086, COSV99896978; called by muse, mutect2, varscan2
- PRKDC | c.7798A>G p.T2600A | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated (0.45); PolyPhen benign (0.031); catalogued as COSV100039561; called by muse, mutect2, varscan2
- PRKDC | c.5761G>A p.D1921N | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.932); catalogued as rs373832970; called by muse, mutect2, varscan2
- PRM3 | c.106A>G p.M36V | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV99617585; called by muse, mutect2, varscan2
- PRPS1L1 | c.647C>T p.A216V | Missense Mutation (SNP) | VAF 17/142 reads (12%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.508); catalogued as COSV101552925; called by muse, mutect2, varscan2
- PRTN3 | c.227T>C p.I76T | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.6); PolyPhen benign (0.045); catalogued as COSV99311498; called by muse, mutect2, varscan2
- PSMD1 | c.124G>A p.V42I | Missense Mutation (SNP) | VAF 88/300 reads (29%) | SIFT tolerated (0.95); PolyPhen benign (0.001); catalogued as rs776542337, COSV58078450, COSV58083546; called by muse, mutect2, varscan2
- PSMD3 | c.716C>T p.T239M | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.684); catalogued as rs148147676; called by muse, mutect2, varscan2
- PSME2 | c.511C>T p.R171C | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); catalogued as rs150829665, COSV99395570; called by muse, mutect2, varscan2
- PTGDR2 | c.440C>T p.A147V | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as rs370596613, COSV99920110; called by muse, mutect2, varscan2
- PTPN7 | c.802C>G p.L268V (on ENST00000495688; = p.L307V on NM_002832.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.799); catalogued as COSV100459774; called by muse, mutect2
- PTPRF | c.1406C>T p.A469V | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.255); catalogued as rs1031553811, COSV100740783; called by muse, mutect2, varscan2
- PTPRK | c.3040G>A p.V1014I (on ENST00000368215 / NM_001291984.2; = p.V1015I on NM_002844.4) | Missense Mutation (SNP) | VAF 57/244 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.029); catalogued as rs1354520365, COSV100950708; called by muse, mutect2, varscan2
- PTPRT | c.3629A>G p.D1210G | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV100626371; called by muse, mutect2, varscan2
- PXN | c.1025A>G p.Q342R (on ENST00000228307 / NM_001080855.3; = p.Q308R on NM_002859.4) | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.917); catalogued as COSV57218489; called by muse, mutect2, varscan2
- PYGO2 | c.326del p.G109Afs*52 | Frame Shift Del (DEL) | VAF 12/37 reads (32%) | catalogued as COSV63757621; called by mutect2, pindel, varscan2
- QSER1 | c.5090del p.N1697Mfs*4 (on ENST00000399302; = p.N1826Mfs*4 on NM_001076786.3) | Frame Shift Del (DEL) | VAF 90/310 reads (29%) | catalogued as rs754588466; called by mutect2, varscan2
- RAB34 | c.560C>A p.A187D | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); catalogued as COSV56386423; called by muse, mutect2, varscan2
- RAB3IL1 | c.934C>A p.R312S | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.129); catalogued as COSV100076520; called by muse, mutect2, varscan2
- RAD51AP2 | c.357del p.S120Hfs*8 | Frame Shift Del (DEL) | VAF 15/50 reads (30%) | catalogued as rs750569378, COSV67588127; called by mutect2, pindel, varscan2
- RAPGEF3 | c.743A>G p.H248R (on ENST00000389212; = p.H206R on NM_006105.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/204 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV50206052, COSV99406093; called by muse, mutect2, varscan2
- RASA1 | c.2513del p.N838Mfs*4 | Frame Shift Del (DEL) | VAF 84/310 reads (27%) | catalogued as rs1561325048; called by mutect2, pindel, varscan2
- RASSF3 | c.635A>G p.Q212R | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.986); catalogued as rs1328043971, COSV99309304; called by muse, mutect2, varscan2
- RASSF7 | c.586C>G p.L196V | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.628); catalogued as rs1412267353, COSV100272522; called by muse, mutect2, varscan2
- RBL2 | c.1111G>A p.A371T | Missense Mutation (SNP) | VAF 35/98 reads (36%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs371003080; called by muse, mutect2, varscan2
- RBM17 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs753761759, COSV101159071; called by muse, mutect2, varscan2
- RBMX2 | c.506del p.K169Rfs*26 | Frame Shift Del (DEL) | VAF 43/170 reads (25%) | catalogued as rs1556362812; called by mutect2, varscan2
- RBPJ | c.673T>C p.L225= | Splice Region (SNP) | VAF 33/126 reads (26%) | catalogued as COSV60752494; called by muse, mutect2, varscan2
- RCN3 | c.358G>A p.A120T | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.102); catalogued as COSV99571249; called by muse, mutect2, varscan2
- RELN | c.3028C>T p.R1010C | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs375752077; called by muse, mutect2, varscan2
- RETREG1 | c.979C>T p.P327S (on ENST00000306320 / NM_001034850.2; = p.P186S on NM_019000.4) | Missense Mutation (SNP) | VAF 40/136 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV100104065; called by muse, mutect2, varscan2
- RGS12 | c.3870del p.Q1292Rfs*49 | Frame Shift Del (DEL) | VAF 14/38 reads (37%) | catalogued as rs751982308; called by mutect2, varscan2
- RGS3 | c.1228T>C p.C410R (on ENST00000350696 / NM_001282923.2; = p.C298R on NM_017790.4) | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.312); catalogued as COSV100464948; called by muse, mutect2, varscan2
- RGS6 | c.652C>T p.R218* | Nonsense Mutation (SNP) | VAF 68/216 reads (31%) | catalogued as rs200924429, COSV59573357; called by muse, mutect2, varscan2
- RNASEL | c.1930dup p.M644Nfs*3 | Frame Shift Ins (INS) | VAF 42/140 reads (30%) | catalogued as rs1192139971; called by mutect2, varscan2
- RND1 | c.389G>A p.R130Q | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs267603489, COSV59045087; called by muse, mutect2, varscan2
- RNF113B | c.910G>A p.A304T | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs774767836, COSV57434757; called by muse, mutect2, varscan2
- RNF139 | c.190G>A p.A64T | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as COSV99413278; called by muse, mutect2, varscan2
- RNF39 | c.1195C>T p.R399C | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.588); catalogued as rs142632327; called by muse, mutect2, varscan2
- RNF41 | c.362G>A p.G121D | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as COSV61504359; called by muse, mutect2, varscan2
- ROBO1 | c.40C>A p.L14I | Missense Mutation (SNP) | VAF 33/125 reads (26%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.009); catalogued as COSV71968245; called by muse, mutect2, varscan2
- ROBO3 | c.353T>C p.L118P | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1454593420, COSV67299689; called by muse, mutect2, varscan2
- RP1L1 | c.2663C>T p.P888L | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as rs894409098, COSV66758027; called by muse, mutect2, varscan2
- RPA4 | c.713C>T p.A238V | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.033); catalogued as COSV100232092; called by muse, mutect2, varscan2
- RPH3A | c.611-1G>T p.X204_splice (on ENST00000389385 / NM_001143854.2; = p.X200_splice on NM_014954.4 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 23/114 reads (20%) | catalogued as COSV101231795; called by muse, mutect2, varscan2
- RPL34 | c.325G>A p.A109T | Missense Mutation (SNP) | VAF 49/174 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV101158421; called by muse, mutect2, varscan2
- RRAS | c.635del p.G212Afs*22 | Frame Shift Del (DEL) | VAF 13/62 reads (21%) | catalogued as COSV55868923; called by mutect2, pindel, varscan2
- RRBP1 | c.2509G>T p.E837* (on ENST00000377813 / NM_001365613.2; = p.E404* on NM_004587.3) | Nonsense Mutation (SNP) | VAF 19/70 reads (27%) | catalogued as COSV55699297; called by muse, mutect2, varscan2
- RREB1 | c.2090G>A p.R697Q | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58557005; called by muse, mutect2, varscan2
- RS1 | c.572G>A p.R191Q | Missense Mutation (SNP) | VAF 32/98 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1402116265, CM136243, COSV66107582; called by muse, mutect2, varscan2
- RSPH10B | c.2345C>T p.A782V | Missense Mutation (SNP) | VAF 105/686 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1562555346, COSV100382772; called by muse, mutect2, varscan2
- RTF1 | c.1658G>A p.R553Q | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as COSV67477976; called by muse, mutect2, varscan2
- RTN4 | c.1489del p.I497* | Frame Shift Del (DEL) | VAF 9/30 reads (30%) | catalogued as rs761969807; called by mutect2, varscan2
- RUNX2 | c.607G>A p.V203I | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.919); catalogued as rs147009083, COSV61844130; called by muse, mutect2, varscan2
- RXFP1 | c.1820A>G p.H607R | Missense Mutation (SNP) | VAF 59/231 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0.085); catalogued as COSV100313655; called by muse, mutect2, varscan2
- RYR1 | c.4072G>C p.G1358R | Missense Mutation (SNP) | VAF 61/173 reads (35%) | SIFT tolerated (0.22); PolyPhen benign (0.097); catalogued as COSV100615307; called by muse, mutect2, varscan2
- RYR2 | c.3371C>T p.P1124L | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs779640835, COSV100769203, COSV63662051; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RYR2 | c.13982A>G p.Y4661C | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.995); catalogued as COSV100769205; called by muse, mutect2, varscan2
- SALL1 | c.1682del p.P561Qfs*45 | Frame Shift Del (DEL) | VAF 11/48 reads (23%) | catalogued as COSV51764199; called by mutect2, pindel, varscan2
- SAMD9L | c.2668A>G p.M890V | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.509); catalogued as COSV100560550; called by muse, mutect2, varscan2
- SCAF4 | c.1175A>G p.Q392R | Missense Mutation (SNP) | VAF 10/176 reads (6%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.091); catalogued as COSV99741234; called by muse, mutect2
- SCAF4 | c.749del p.P250Hfs*96 | Frame Shift Del (DEL) | VAF 17/74 reads (23%) | catalogued as COSV54589079; called by mutect2, pindel, varscan2
- SCAF8 | c.566C>T p.A189V | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.06); catalogued as rs749076389, COSV100914024; called by muse, mutect2, varscan2
- SCAPER | c.2613del p.A872Pfs*4 | Frame Shift Del (DEL) | VAF 23/65 reads (35%) | catalogued as rs757259031; called by mutect2, varscan2
- SCFD2 | c.890T>G p.L297R | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as COSV101189323; called by muse, mutect2, varscan2
- SCLY | c.311C>T p.T104I (on ENST00000651534; = p.T96I on NM_016510.7) | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99615490; called by muse, mutect2, varscan2
- SCN1B | c.593C>T p.S198L | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0.153); catalogued as rs764539405, COSV52883367; called by muse, mutect2, varscan2
- SCN3A | c.4757C>T p.T1586I | Missense Mutation (SNP) | VAF 36/139 reads (26%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.905); catalogued as rs778468833, COSV99326396; called by muse, mutect2, varscan2
- SCN7A | c.2480T>C p.I827T | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.506); catalogued as COSV101313153; called by muse, mutect2, varscan2
- SCUBE2 | c.1289A>G p.H430R | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV100496519; called by muse, mutect2, varscan2
- SDK2 | c.2364G>T p.Q788H | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV101167258; called by muse, mutect2, varscan2
- SDK2 | c.1409C>T p.A470V | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.21); catalogued as rs572942777, COSV66181469, COSV66185292; called by muse, mutect2, varscan2
- SEC31A | c.1384del p.I462Lfs*16 | Frame Shift Del (DEL) | VAF 22/64 reads (34%) | catalogued as rs748463349, COSV52348607; called by mutect2, varscan2
- SERPINB9 | c.487A>G p.N163D | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.603); catalogued as COSV101046538; called by muse, mutect2, varscan2
- SERPINF1 | c.397del p.Q133Rfs*18 | Frame Shift Del (DEL) | VAF 17/61 reads (28%) | catalogued as COSV99628862; called by mutect2, pindel, varscan2
- SERTAD1 | c.550A>C p.N184H | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV100781675; called by muse, mutect2, varscan2
- SETMAR | c.1951G>T p.E651* | Nonsense Mutation (SNP) | VAF 16/63 reads (25%) | catalogued as COSV100740852; called by muse, mutect2, varscan2
- SF3B1 | c.146G>T p.S49I | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.125); catalogued as COSV100134295; called by muse, mutect2, varscan2
- SFMBT1 | c.772C>T p.P258S | Missense Mutation (SNP) | VAF 41/146 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs1389189429, COSV99965938; called by muse, mutect2, varscan2
- SHANK3 | c.5075T>C p.L1692P | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.127); catalogued as COSV99436669; called by muse, mutect2, varscan2
- SHC1 | c.1087del p.V363Wfs*2 (on ENST00000368445 / NM_183001.5; = p.V253Wfs*2 on NM_003029.5) | Frame Shift Del (DEL) | VAF 45/98 reads (46%) | catalogued as rs746556543; called by mutect2, varscan2
- SHPRH | c.4093C>T p.R1365C (on ENST00000275233 / NM_001042683.3; = p.R1369C on NM_173082.3) | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1378058905, COSV51609268; called by muse, mutect2, varscan2
- SIGLEC1 | c.4717G>A p.V1573M | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.985); catalogued as rs534114180, COSV99163819; called by muse, mutect2, varscan2
- SIK2 | c.1615A>G p.M539V | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100516092; called by muse, mutect2, varscan2
- SIK3 | c.2126A>G p.D709G (on ENST00000445177 / NM_001366686.2; = p.D667G on NM_025164.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/81 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.964); catalogued as COSV99407664; called by muse, mutect2
- SIN3B | c.2607G>T p.E869D | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99931571; called by muse, mutect2, varscan2
- SKA3 | c.502G>A p.V168I | Missense Mutation (SNP) | VAF 66/193 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs146011474; called by muse, mutect2, varscan2
- SKAP1 | c.443-1G>A p.X148_splice | Splice Site (SNP) | VAF 29/86 reads (34%) | catalogued as COSV100411631; called by muse, mutect2, varscan2
- SLC12A7 | c.2056del p.H686Tfs*11 | Frame Shift Del (DEL) | VAF 22/75 reads (29%) | catalogued as rs767964038; called by mutect2, pindel, varscan2
- SLC16A1 | c.494A>G p.N165S | Missense Mutation (SNP) | VAF 4/77 reads (5%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.764); catalogued as rs1001233585, COSV100855907; called by muse, mutect2
- SLC16A3 | c.701C>T p.A234V | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV101125895; called by muse, mutect2, varscan2
- SLC1A6 | c.413C>T p.T138I | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.914); catalogued as COSV99693567; called by muse, mutect2, varscan2
- SLC22A11 | c.568G>A p.A190T | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.328); catalogued as rs762015245, COSV100102252, COSV57254663; called by muse, mutect2, varscan2
- SLC25A3 | c.607G>A p.A203T (on ENST00000228318 / NM_005888.3; = p.A202T on NM_002635.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 41/214 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.845); catalogued as COSV51845053; called by muse, mutect2, varscan2
- SLC2A9 | c.1575G>T p.E525D | Missense Mutation (SNP) | VAF 43/123 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.048); catalogued as COSV99304336; called by muse, mutect2, varscan2
- SLC30A3 | c.617G>A p.S206N | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.627); catalogued as COSV99273560; called by muse, mutect2, varscan2
- SLC30A9 | c.1289T>C p.V430A | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100048085; called by muse, mutect2, varscan2
- SLC35B3 | c.608C>T p.A203V | Missense Mutation (SNP) | VAF 39/170 reads (23%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.679); catalogued as COSV100217246; called by muse, mutect2, varscan2
- SLC35G3 | c.733G>A p.V245M | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as rs746447506, COSV52011086; called by muse, mutect2, varscan2
- SLC43A2 | c.380C>T p.A127V | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.067); catalogued as rs200135342, COSV100024844; called by muse, mutect2, varscan2
- SLC4A10 | c.2207C>T p.T736I (on ENST00000446997 / NM_001354461.2; = p.T706I on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99763265; called by muse, mutect2, varscan2
- SLC5A6 | c.1888C>T p.L630F | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.296); catalogued as rs1480675291, COSV100143179; called by muse, mutect2, varscan2
- SLC5A7 | c.1678A>G p.K560E | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as rs770906251, COSV99886493; called by muse, mutect2, varscan2
- SLC6A15 | c.1024T>G p.F342V | Missense Mutation (SNP) | VAF 9/187 reads (5%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV99880489; called by muse, mutect2
- SLC9A5 | c.2080+1G>A p.X694_splice | Splice Site (SNP) | VAF 20/58 reads (34%) | catalogued as COSV100237199; called by muse, mutect2, varscan2
- SLCO1B3 | c.977del p.F326Sfs*4 | Frame Shift Del (DEL) | VAF 15/108 reads (14%) | catalogued as rs769005039, COSV53944787; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
706 further variants in this file (379 protein-altering or splice-affecting, 302 silent, 25 other) are not listed here.
